Somatic mutation profile of tumor specimen TCGA-HU-A4H4-01A (aliquot TCGA-HU-A4H4-01A-21D-A25D-08) from TCGA case TCGA-HU-A4H4, project TCGA-STAD (Stomach Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Tubular adenocarcinoma; Tissue or organ of origin: Gastric antrum; AJCC pathologic stage: Stage IIB; Tumor grade: G3; Age at diagnosis: 53.8 years (19,665 days).
Specimen TCGA-HU-A4H4-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) efbd9019-cb8c-4932-87f2-d566bda9dc79.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-HU-A4H4-11A (Solid Tissue Normal), aliquot TCGA-HU-A4H4-11A-11D-A25E-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/5baaf78f-9083-4d53-8aab-9a7121fb5bd3

The open-access MAF lists 724 somatic variants for this specimen: 540 protein-altering or splice-affecting, 168 silent, 16 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 426, Silent 168, Frame Shift Del 67, Frame Shift Ins 18, Nonsense Mutation 14, Intron 10, Splice Site 9, RNA 5, In Frame Del 3, Splice Region 3, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- DOK7 | c.1263del p.S422Hfs*34 | Frame Shift Del (DEL) | VAF 5/30 reads (17%) | catalogued as rs606231129; ClinVar: pathogenic; called by pindel, varscan2
- PIK3CA | c.3140A>G p.H1047R | Missense Mutation (SNP) | VAF 29/134 reads (22%) | hotspot (GDC flag); SIFT tolerated (0.11); PolyPhen benign (0.085); catalogued as rs121913279, CM153086, COSV55873195, COSV55873401, COSV55888015; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- SMAD4 | c.1082G>A p.R361H | Missense Mutation (SNP) | VAF 14/68 reads (21%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs377767347, CM004254, CM100519, COSV61684056, COSV61686014, COSV61689167; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- SON | c.384del p.K128Nfs*21 | Frame Shift Del (DEL) | VAF 10/34 reads (29%) | catalogued as rs778418096, COSV51650596; ClinVar: pathogenic; called by mutect2, varscan2
- TP53 | c.808T>C p.F270L | Missense Mutation (SNP) | VAF 8/25 reads (32%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs1057519988, CM161002, COSV52691720, COSV52697968, COSV52744290; ClinVar: likely pathogenic; called by muse, mutect2
- ABCB10 | c.1162G>A p.A388T | Missense Mutation (SNP) | VAF 20/105 reads (19%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.589); catalogued as COSV60619604; called by muse, mutect2, varscan2
- ABCC5 | c.4114A>G p.I1372V | Missense Mutation (SNP) | VAF 9/116 reads (8%) | SIFT tolerated (0.1); PolyPhen benign (0.406); catalogued as COSV55586842; called by muse, mutect2
- ABCG4 | c.1708T>C p.Y570H | Missense Mutation (SNP) | VAF 36/299 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV56641881; called by muse, mutect2, varscan2
- AC013489.1 | c.208C>T p.R70C | Missense Mutation (SNP) | VAF 28/122 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.642); catalogued as rs180884171; called by muse, mutect2, varscan2
- ACTB | c.962C>T p.A321V | Missense Mutation (SNP) | VAF 16/152 reads (11%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.066); catalogued as COSV59316606; called by muse, mutect2
- ADA | c.1011A>C p.E337D | Missense Mutation (SNP) | VAF 13/139 reads (9%) | SIFT tolerated (0.16); PolyPhen benign (0.003); catalogued as COSV63068660; called by muse, mutect2
- ADA | c.664G>A p.E222K | Missense Mutation (SNP) | VAF 18/167 reads (11%) | SIFT tolerated (0.51); PolyPhen benign (0.003); catalogued as rs371353841; called by muse, mutect2, varscan2
- ADAD1 | c.1616A>C p.K539T | Missense Mutation (SNP) | VAF 7/30 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56641326; called by muse, mutect2, varscan2
- ADAM11 | c.468-1G>T p.X156_splice | Splice Site (SNP) | VAF 12/61 reads (20%) | catalogued as COSV52344203; called by muse, mutect2, varscan2
- ADAMTS18 | c.3065C>T p.A1022V | Missense Mutation (SNP) | VAF 16/117 reads (14%) | SIFT tolerated (0.29); PolyPhen benign (0.005); catalogued as rs1186864593, COSV51398454; called by muse, mutect2, varscan2
- ADAMTS7 | c.3721C>T p.P1241S | Missense Mutation (SNP) | VAF 5/37 reads (14%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.84); catalogued as COSV101183163, COSV66305796; called by mutect2, varscan2
- ADGRF2 | c.1630C>A p.L544I (on ENST00000296862 / NM_001368115.2; = p.L476I on NM_153839.7) | Missense Mutation (SNP) | VAF 8/78 reads (10%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.615); catalogued as rs776318670, COSV57286358, COSV57287234; called by mutect2, varscan2
- AGO4 | c.994G>A p.E332K | Missense Mutation (SNP) | VAF 26/101 reads (26%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.983); catalogued as COSV64616349; called by muse, mutect2, varscan2
- AHCTF1 | c.1399T>C p.S467P (on ENST00000366508; = p.S441P on NM_015446.5) | Missense Mutation (SNP) | VAF 32/203 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV58245550; called by muse, mutect2, varscan2
- AKAP4 | c.1912C>T p.L638F | Missense Mutation (SNP) | VAF 21/162 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); catalogued as COSV62073594; called by muse, mutect2, varscan2
- ALKBH1 | c.1100C>T p.T367I | Missense Mutation (SNP) | VAF 10/118 reads (8%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.009); catalogued as COSV53658731; called by muse, mutect2
- ALMS1 | c.9964G>A p.D3322N | Missense Mutation (SNP) | VAF 6/110 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as COSV52502081; called by muse, mutect2
- ALOX15 | c.1349G>A p.R450Q | Missense Mutation (SNP) | VAF 20/49 reads (41%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs776154712, COSV53396002; called by muse, mutect2, varscan2
- AMY2B | c.970G>T p.G324* | Nonsense Mutation (SNP) | VAF 55/346 reads (16%) | catalogued as COSV63713938, COSV63716719; called by muse, mutect2, varscan2
- ANK3 | c.11156G>A p.R3719H | Missense Mutation (SNP) | VAF 30/269 reads (11%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.996); catalogued as rs748061808, COSV55043282; called by muse, mutect2, varscan2
- ANK3 | c.7016A>G p.Q2339R | Missense Mutation (SNP) | VAF 7/159 reads (4%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.039); catalogued as COSV55043289; called by muse, mutect2
- ANKLE2 | c.2237G>A p.R746H | Missense Mutation (SNP) | VAF 39/102 reads (38%) | SIFT tolerated (0.08); PolyPhen benign (0.003); catalogued as rs775374422, COSV61707711; called by muse, mutect2, varscan2
- ANKRD50 | c.4172A>G p.Q1391R | Missense Mutation (SNP) | VAF 8/116 reads (7%) | SIFT tolerated, low confidence (0.49); PolyPhen possibly damaging (0.901); catalogued as COSV72385012; called by muse, mutect2
- ANKS1A | c.2690C>T p.A897V | Missense Mutation (SNP) | VAF 7/57 reads (12%) | SIFT tolerated (0.58); PolyPhen benign (0); catalogued as rs779234201, COSV64458664; called by muse, mutect2
- AQR | c.2869A>G p.T957A | Missense Mutation (SNP) | VAF 7/60 reads (12%) | SIFT tolerated (0.71); PolyPhen benign (0.003); catalogued as COSV50029472; called by muse, mutect2, varscan2
- ARL8A | c.41C>T p.A14V | Missense Mutation (SNP) | VAF 6/71 reads (8%) | SIFT deleterious (0.02); PolyPhen benign (0.015); catalogued as rs888265000, COSV55342687; called by muse, mutect2
- ASAP2 | c.290C>T p.A97V | Missense Mutation (SNP) | VAF 6/64 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs568509831, COSV55626960; called by mutect2, varscan2
- ASB6 | c.356T>C p.V119A | Missense Mutation (SNP) | VAF 8/42 reads (19%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.997); catalogued as COSV52964340; called by muse, mutect2, varscan2
- ASH1L | c.7702A>G p.S2568G (on ENST00000368346 / NM_001366177.2; = p.S2563G on NM_018489.3) | Missense Mutation (SNP) | VAF 11/296 reads (4%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.351); catalogued as COSV64205254; called by muse, mutect2
- ASIC3 | c.35G>A p.R12Q | Missense Mutation (SNP) | VAF 11/84 reads (13%) | SIFT tolerated (0.27); PolyPhen benign (0.001); catalogued as rs532400592, COSV52501956; called by muse, mutect2, varscan2
- ASTL | c.492G>T p.Q164H | Missense Mutation (SNP) | VAF 9/107 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV60903488; called by muse, mutect2
- ATP13A3 | c.1900C>T p.R634C | Missense Mutation (SNP) | VAF 22/113 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs779570755, COSV55461347; called by muse, mutect2, varscan2
- ATP6V1B1 | c.197T>C p.V66A | Missense Mutation (SNP) | VAF 7/35 reads (20%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.995); catalogued as rs781977744, COSV52268146; called by muse, mutect2, varscan2
- B3GNT2 | c.937G>A p.G313S | Missense Mutation (SNP) | VAF 14/108 reads (13%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.964); catalogued as rs530636212, COSV57343753; called by muse, mutect2, varscan2
- BAHCC1 | c.7609A>G p.I2537V | Missense Mutation (SNP) | VAF 6/94 reads (6%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.856); catalogued as COSV57022517; called by muse, mutect2
- BAZ1A | c.1241C>A p.T414K | Missense Mutation (SNP) | VAF 10/85 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.454); catalogued as COSV62408879; called by muse, mutect2, varscan2
- BCL6B | c.1229A>C p.K410T | Missense Mutation (SNP) | VAF 7/76 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV53426136; called by muse, mutect2, varscan2
- BIRC6 | c.4303A>G p.N1435D | Missense Mutation (SNP) | VAF 3/16 reads (19%) | SIFT tolerated (0.35); PolyPhen probably damaging (0.997); catalogued as COSV70195352; called by muse, mutect2
- BLMH | c.313del p.W105Gfs*11 | Frame Shift Del (DEL) | VAF 8/40 reads (20%) | catalogued as COSV55587541; called by mutect2, pindel, varscan2
- BRSK2 | c.1727C>A p.A576D | Missense Mutation (SNP) | VAF 5/21 reads (24%) | SIFT tolerated (0.17); PolyPhen benign (0.066); catalogued as COSV57539779; called by muse, mutect2, varscan2
- BTAF1 | c.4110G>T p.Q1370H | Missense Mutation (SNP) | VAF 14/90 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.463); catalogued as COSV56429606; called by muse, mutect2, varscan2
- BTBD7 | c.1853C>T p.A618V | Missense Mutation (SNP) | VAF 27/200 reads (14%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.978); catalogued as rs866089872, COSV58283031; called by muse, mutect2, varscan2
- BTN3A1 | c.1004C>T p.A335V | Missense Mutation (SNP) | VAF 21/125 reads (17%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.994); catalogued as rs574630664, COSV50024434; called by muse, mutect2, varscan2
- BUB1 | c.896A>C p.K299T | Missense Mutation (SNP) | VAF 11/49 reads (22%) | SIFT tolerated (0.15); PolyPhen benign (0.01); catalogued as COSV57061060; called by muse, mutect2, varscan2
- C11orf68 | c.248G>T p.G83V (on ENST00000530188; = p.G124V on NM_031450.4) | Missense Mutation (SNP) | VAF 13/59 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV56987807; called by muse, mutect2, varscan2
- C1orf115 | c.350T>C p.V117A | Missense Mutation (SNP) | VAF 12/156 reads (8%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.655); catalogued as COSV54273297; called by muse, mutect2
- CACHD1 | c.3704del p.P1235Lfs*7 | Frame Shift Del (DEL) | VAF 11/92 reads (12%) | catalogued as rs764948820; called by mutect2, varscan2
- CAMKK1 | c.457C>T p.H153Y | Missense Mutation (SNP) | VAF 7/39 reads (18%) | SIFT tolerated (1); PolyPhen benign (0.009); catalogued as rs760702571, COSV50113917; called by muse, mutect2, varscan2
- CATSPERE | c.854G>A p.R285Q | Missense Mutation (SNP) | VAF 15/197 reads (8%) | SIFT tolerated (0.23); PolyPhen benign (0); catalogued as rs746513331, COSV63675728; called by muse, mutect2
- CBLN2 | c.229G>A p.A77T | Missense Mutation (SNP) | VAF 7/17 reads (41%) | SIFT tolerated (0.33); PolyPhen benign (0.003); catalogued as COSV54050178, COSV99504092; called by muse, mutect2, varscan2
- CCDC114 | c.1297T>C p.F433L | Missense Mutation (SNP) | VAF 6/66 reads (9%) | SIFT tolerated (0.34); PolyPhen benign (0); catalogued as rs1451444130, COSV59555176; called by muse, mutect2
- CCDC153 | c.599dup p.G201Wfs*9 | Frame Shift Ins (INS) | VAF 22/202 reads (11%) | catalogued as rs745729530; called by mutect2, varscan2
- CCDC7 | c.4130G>C p.R1377P | Missense Mutation (SNP) | VAF 12/88 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.963); catalogued as COSV56536107, COSV56540034; called by muse, mutect2, varscan2
- CCNB3 | c.3410T>C p.M1137T | Missense Mutation (SNP) | VAF 8/102 reads (8%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.841); catalogued as COSV52069714; called by muse, mutect2
- CCT6B | c.724A>C p.T242P | Missense Mutation (SNP) | VAF 6/23 reads (26%) | SIFT tolerated (0.05); PolyPhen benign (0.104); catalogued as COSV58487728; called by muse, mutect2, varscan2
- CD1B | c.794C>G p.A265G | Missense Mutation (SNP) | VAF 16/134 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.436); catalogued as COSV63805099; called by muse, mutect2
- CDH13 | c.1120G>A p.E374K | Missense Mutation (SNP) | VAF 11/46 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV51788854; called by muse, mutect2, varscan2
- CDH18 | c.1579C>T p.L527F | Missense Mutation (SNP) | VAF 12/74 reads (16%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.521); catalogued as rs765442242, COSV56900075, COSV99938322; called by muse, mutect2, varscan2
- CDH4 | c.1241C>T p.T414M | Missense Mutation (SNP) | VAF 17/67 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1200506111, COSV64641310; called by muse, mutect2, varscan2
- CDK12 | c.4336G>T p.G1446* (on ENST00000447079 / NM_016507.4; = p.G1437* on NM_015083.3) | Nonsense Mutation (SNP) | VAF 5/99 reads (5%) | catalogued as COSV70999152; called by muse, mutect2
- CDK13 | c.1178G>A p.R393H | Missense Mutation (SNP) | VAF 10/118 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV51696193; called by muse, mutect2
- CDK13 | c.1243T>C p.Y415H | Missense Mutation (SNP) | VAF 10/95 reads (11%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.96); catalogued as COSV51696212; called by muse, mutect2, varscan2
- CDON | c.3025G>T p.G1009* | Nonsense Mutation (SNP) | VAF 10/116 reads (9%) | catalogued as COSV54994889, COSV54999553; called by muse, mutect2
- CENPF | c.3758T>C p.M1253T | Missense Mutation (SNP) | VAF 18/84 reads (21%) | SIFT tolerated (0.74); PolyPhen benign (0); catalogued as COSV65272507; called by muse, mutect2, varscan2
- CEP97 | c.928A>G p.N310D | Missense Mutation (SNP) | VAF 14/68 reads (21%) | SIFT tolerated (0.07); PolyPhen benign (0.003); catalogued as COSV59122570; called by muse, mutect2, varscan2
- CFAP206 | c.395G>A p.R132Q | Missense Mutation (SNP) | VAF 7/63 reads (11%) | SIFT tolerated (0.23); PolyPhen benign (0.007); catalogued as rs371084143, COSV99739571; called by muse, mutect2, varscan2
- CHD6 | c.1477A>G p.T493A | Missense Mutation (SNP) | VAF 19/234 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58553581; called by muse, mutect2
- CHD8 | c.1477C>T p.R493W (on ENST00000646647 / NM_001170629.2; = p.R214W on NM_020920.4) | Missense Mutation (SNP) | VAF 32/75 reads (43%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.859); catalogued as rs774630592, COSV67869622; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CHD9 | c.4212G>A p.A1404= | Splice Region (SNP) | VAF 15/85 reads (18%) | catalogued as rs756000122, COSV54607453; called by muse, mutect2, varscan2
- CHPF2 | c.1941del p.S648Pfs*13 | Frame Shift Del (DEL) | VAF 10/53 reads (19%) | catalogued as rs746469175; called by mutect2, pindel, varscan2
- CHRDL1 | c.1169A>G p.K390R (on ENST00000372045; = p.K396R on NM_145234.4) | Missense Mutation (SNP) | VAF 12/97 reads (12%) | SIFT tolerated (0.16); PolyPhen benign (0.287); catalogued as COSV54322591, COSV54327607; called by muse, mutect2, varscan2
- CHST1 | c.169C>A p.L57I | Missense Mutation (SNP) | VAF 14/88 reads (16%) | SIFT tolerated (0.24); PolyPhen benign (0.003); catalogued as rs750018576, COSV57321651; called by muse, mutect2, varscan2
- CHST4 | c.22A>G p.K8E | Missense Mutation (SNP) | VAF 25/108 reads (23%) | SIFT tolerated (0.86); PolyPhen benign (0.015); catalogued as COSV58296420; called by muse, mutect2, varscan2
- CIART | c.687G>A p.M229I | Missense Mutation (SNP) | VAF 21/164 reads (13%) | SIFT tolerated (0.41); PolyPhen benign (0); catalogued as COSV51743078; called by muse, mutect2, varscan2
- CLASP1 | c.3794A>G p.N1265S | Missense Mutation (SNP) | VAF 15/134 reads (11%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as COSV55312770, COSV55328209; called by muse, mutect2, varscan2
- CLCNKA | c.491G>A p.G164D | Missense Mutation (SNP) | VAF 5/77 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV58890303; called by muse, mutect2
- CNOT1 | c.2706del p.Q904Sfs*9 | Frame Shift Del (DEL) | VAF 21/157 reads (13%) | catalogued as rs1397135931, COSV55313852; called by mutect2, pindel, varscan2
- CNTN1 | c.767G>A p.G256D | Missense Mutation (SNP) | VAF 39/245 reads (16%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.537); catalogued as COSV61635594, COSV61635910; called by muse, mutect2, varscan2
- CNTNAP3 | c.2530C>A p.L844M | Missense Mutation (SNP) | VAF 8/50 reads (16%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.934); catalogued as COSV52663424; called by muse, mutect2, varscan2
- COL27A1 | c.460G>A p.G154R | Missense Mutation (SNP) | VAF 10/61 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1044459381, COSV61921277; called by muse, mutect2, varscan2
- COL2A1 | c.197A>G p.D66G | Missense Mutation (SNP) | VAF 5/95 reads (5%) | SIFT deleterious (0.02); PolyPhen benign (0.115); catalogued as COSV61527641; called by muse, mutect2
- COL4A3 | c.4224del p.G1409Afs*20 | Frame Shift Del (DEL) | VAF 12/52 reads (23%) | catalogued as COSV101170464; called by mutect2, pindel, varscan2
- COL5A1 | c.5230T>C p.Y1744H | Missense Mutation (SNP) | VAF 5/38 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV65664772; called by muse, mutect2
- COL6A3 | c.1792G>A p.D598N | Missense Mutation (SNP) | VAF 9/71 reads (13%) | SIFT tolerated (0.11); PolyPhen benign (0.141); catalogued as rs778400474, COSV55078994; called by muse, mutect2, varscan2
- COPE | c.98A>G p.Q33R | Missense Mutation (SNP) | VAF 9/69 reads (13%) | SIFT tolerated (0.07); PolyPhen benign (0.201); catalogued as COSV53229396; called by muse, mutect2, varscan2
- CREB5 | c.1364-2A>G p.X455_splice (on ENST00000357727 / NM_182898.4; = p.X448_splice on NM_004904.3) | Splice Site (SNP) | VAF 10/192 reads (5%) | catalogued as rs1430755678, COSV63217278; called by muse, mutect2
- CREM | c.742G>A p.G248S (on ENST00000429130; = p.G203S on NM_181571.3) | Missense Mutation (SNP) | VAF 28/356 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.376); catalogued as COSV59764887, COSV59764979; called by muse, mutect2
- CSHL1 | c.164A>C p.Q55P | Missense Mutation (SNP) | VAF 10/274 reads (4%) | SIFT deleterious (0.03); PolyPhen benign (0.214); catalogued as COSV51987134; called by muse, mutect2
- CSPG5 | c.292A>G p.T98A | Missense Mutation (SNP) | VAF 5/71 reads (7%) | SIFT tolerated, low confidence (0.44); PolyPhen benign (0.005); catalogued as COSV53129821; called by muse, mutect2
- CSPP1 | c.3318T>G p.S1106R (on ENST00000676605; = p.S1065R on NM_024790.6) | Missense Mutation (SNP) | VAF 20/61 reads (33%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.883); catalogued as COSV51579912; called by muse, mutect2, varscan2
- CYP26B1 | c.307C>T p.R103C | Missense Mutation (SNP) | VAF 20/114 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.226); catalogued as COSV50010649; called by muse, varscan2
- CYSTM1 | c.168G>T p.Q56H | Missense Mutation (SNP) | VAF 5/57 reads (9%) | SIFT tolerated, low confidence (0.08); PolyPhen possibly damaging (0.601); catalogued as COSV55834036; called by muse, mutect2
- DAB2IP | c.3395A>G p.D1132G (on ENST00000408936; = p.D1104G on NM_032552.3) | Missense Mutation (SNP) | VAF 18/83 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.652); catalogued as COSV52254226; called by muse, mutect2, varscan2
- DAXX | c.355C>T p.R119W | Missense Mutation (SNP) | VAF 10/156 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs773142629, COSV56466378; called by muse, mutect2
- DBNL | c.242T>C p.L81P | Missense Mutation (SNP) | VAF 12/81 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1288054968, COSV68880101; called by muse, mutect2, varscan2
- DDR2 | c.370C>T p.R124W | Missense Mutation (SNP) | VAF 15/77 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM160997, COSV63369117; called by muse, mutect2, varscan2
- DDX1 | c.1326C>A p.H442Q | Missense Mutation (SNP) | VAF 4/75 reads (5%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV51837824; called by muse, mutect2
- DELE1 | c.1378A>G p.N460D | Missense Mutation (SNP) | VAF 20/186 reads (11%) | SIFT tolerated (0.3); PolyPhen benign (0.038); catalogued as COSV51518989; called by muse, mutect2
- DHX30 | c.2902T>C p.Y968H (on ENST00000445061 / NM_138615.3; = p.Y929H on NM_014966.3) | Missense Mutation (SNP) | VAF 10/86 reads (12%) | SIFT tolerated (0.22); PolyPhen benign (0.072); catalogued as rs1559725690, COSV53135217; called by muse, mutect2, varscan2
- DHX36 | c.460del p.M154Cfs*27 | Frame Shift Del (DEL) | VAF 8/48 reads (17%) | catalogued as rs373108427; called by mutect2, varscan2
- DIDO1 | c.622A>G p.T208A | Missense Mutation (SNP) | VAF 10/94 reads (11%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs746361252, COSV56613270; called by muse, mutect2, varscan2
- DLD | c.389C>A p.A130E | Missense Mutation (SNP) | VAF 6/53 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV52736748; called by muse, mutect2, varscan2
- DMBT1 | c.7414C>T p.R2472W (on ENST00000338354 / NM_001377530.1; = p.R1715W on NM_004406.3) | Missense Mutation (SNP) | VAF 8/132 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.787); catalogued as rs867500352, COSV57533469; called by muse, mutect2
- DMD | c.7098+2T>A p.X2366_splice | Splice Site (SNP) | VAF 4/25 reads (16%) | catalogued as COSV58890556, COSV58899298; called by muse, mutect2
- DMRTB1 | c.872C>T p.A291V | Missense Mutation (SNP) | VAF 14/74 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.543); catalogued as rs779900864, COSV65112554; called by muse, varscan2
- DNAH8 | c.13342T>C p.Y4448H | Missense Mutation (SNP) | VAF 16/127 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.766); catalogued as COSV59423338; called by muse, mutect2, varscan2
- DNAJA3 | c.661G>A p.A221T | Missense Mutation (SNP) | VAF 23/95 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.919); catalogued as COSV52160527; called by muse, mutect2, varscan2
- DNAJC11 | c.1396A>G p.N466D | Missense Mutation (SNP) | VAF 23/168 reads (14%) | SIFT tolerated (0.28); PolyPhen benign (0.268); catalogued as COSV50010490; called by muse, mutect2, varscan2
- DNAJC5 | c.76G>A p.A26T | Missense Mutation (SNP) | VAF 9/88 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.595); catalogued as rs753722773, COSV62670706; called by muse, mutect2, varscan2
- DOK5 | c.378A>C p.L126F | Missense Mutation (SNP) | VAF 13/105 reads (12%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.969); catalogued as COSV52816189; called by muse, mutect2, varscan2
- DSCAM | c.1042T>C p.Y348H | Missense Mutation (SNP) | VAF 13/114 reads (11%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.985); catalogued as COSV68020372; called by muse, mutect2
- DSCAML1 | c.2384A>G p.Y795C (on ENST00000321322; = p.Y735C on NM_020693.4) | Missense Mutation (SNP) | VAF 18/78 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.917); catalogued as COSV58380803; called by muse, mutect2, varscan2
- DST | c.9396G>T p.Q3132H | Missense Mutation (SNP) | VAF 22/235 reads (9%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0.007); catalogued as COSV55012368; called by muse, mutect2
- DUOX2 | c.1905A>C p.K635N | Missense Mutation (SNP) | VAF 8/187 reads (4%) | SIFT tolerated (0.3); PolyPhen benign (0.01); catalogued as COSV66530483; called by muse, mutect2
- DVL3 | c.1202T>C p.L401P | Missense Mutation (SNP) | VAF 9/78 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.837); catalogued as COSV100493840, COSV57454741; called by muse, mutect2, varscan2
- DYNC1H1 | c.11479T>C p.Y3827H | Missense Mutation (SNP) | VAF 12/69 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV64134189; called by muse, mutect2, varscan2
- DZIP3 | c.1727T>C p.I576T | Missense Mutation (SNP) | VAF 13/135 reads (10%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.431); catalogued as COSV64311080; called by muse, mutect2
- EDNRB | c.977A>C p.E326A (on ENST00000377211 / NM_001201397.1; = p.E236A on NM_000115.5) | Missense Mutation (SNP) | VAF 22/174 reads (13%) | SIFT tolerated (0.06); PolyPhen benign (0.17); catalogued as COSV57518739; called by muse, mutect2, varscan2
- EEF2 | c.2416G>A p.G806S | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV100500568, COSV58578496; called by muse, mutect2, varscan2
- EFHC1 | c.1298A>G p.D433G | Missense Mutation (SNP) | VAF 18/108 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV64135361; called by muse, mutect2, varscan2
- EIF3B | c.1756C>T p.R586W | Missense Mutation (SNP) | VAF 10/86 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs531111348, COSV62802548; called by muse, mutect2, varscan2
- ENO2 | c.1145C>T p.A382V | Missense Mutation (SNP) | VAF 10/61 reads (16%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.388); catalogued as COSV57544160; called by muse, mutect2, varscan2
- ENTPD1 | c.660A>C p.Q220H | Missense Mutation (SNP) | VAF 14/238 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64599947; called by muse, mutect2
- EPHA3 | c.1363T>G p.L455V | Missense Mutation (SNP) | VAF 22/148 reads (15%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.994); catalogued as COSV60693395; called by muse, mutect2, varscan2
- ERICH3 | c.3725A>T p.E1242V | Missense Mutation (SNP) | VAF 8/86 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.859); catalogued as COSV58598702, COSV58616671; called by muse, mutect2
- ERICH3 | c.665A>C p.Y222S | Missense Mutation (SNP) | VAF 16/110 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.36); catalogued as COSV58598710; called by muse, mutect2, varscan2
- ESRRG | c.1370A>G p.K457R | Missense Mutation (SNP) | VAF 8/68 reads (12%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.783); catalogued as COSV63149033, COSV63153130; called by muse, mutect2, varscan2
- EXD2 | c.1714C>A p.L572M (on ENST00000312994 / NM_001193362.1; = p.L447M on NM_018199.3) | Missense Mutation (SNP) | VAF 4/37 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV57277932; called by muse, mutect2, varscan2
- EXO1 | c.1376T>C p.F459S | Missense Mutation (SNP) | VAF 7/75 reads (9%) | SIFT tolerated (0.91); PolyPhen benign (0); catalogued as COSV62216204; called by muse, mutect2, varscan2
- EXOC4 | c.2065A>G p.N689D | Missense Mutation (SNP) | VAF 26/188 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.972); catalogued as COSV54082830; called by muse, mutect2, varscan2
- F13B | c.104T>G p.I35S | Missense Mutation (SNP) | VAF 9/210 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV66372127; called by muse, mutect2
- FAF1 | c.1601C>T p.A534V | Missense Mutation (SNP) | VAF 27/184 reads (15%) | SIFT tolerated (0.38); PolyPhen possibly damaging (0.714); catalogued as COSV65636020; called by muse, mutect2, varscan2
- FAM81B | c.451A>G p.K151E | Missense Mutation (SNP) | VAF 8/95 reads (8%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.782); catalogued as COSV99352609; called by muse, mutect2
- FCMR | c.86T>C p.L29P | Missense Mutation (SNP) | VAF 19/136 reads (14%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.853); catalogued as COSV65566988; called by muse, mutect2, varscan2
- FER1L6 | c.2799del p.R934Gfs*56 | Frame Shift Del (DEL) | VAF 24/105 reads (23%) | catalogued as rs770147778; called by mutect2, pindel, varscan2
- FETUB | c.437del p.K146Rfs*4 | Frame Shift Del (DEL) | VAF 24/136 reads (18%) | catalogued as rs748969702; called by mutect2, varscan2
- FFAR2 | c.269A>G p.Y90C | Missense Mutation (SNP) | VAF 3/25 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55831665; called by muse, mutect2
- FLG | c.8303A>C p.E2768A | Missense Mutation (SNP) | VAF 52/1294 reads (4%) | SIFT tolerated (0.18); PolyPhen benign (0.286); catalogued as COSV64236095; called by muse, mutect2
- FLG | c.7663G>T p.E2555* | Nonsense Mutation (SNP) | VAF 51/442 reads (12%) | catalogued as rs760728737, COSV64236101, COSV64242040; called by muse, mutect2, varscan2
- FLT4 | c.3499G>T p.E1167* | Nonsense Mutation (SNP) | VAF 17/156 reads (11%) | catalogued as COSV56097810; called by muse, mutect2, varscan2
- FOXI1 | c.397G>A p.A133T | Missense Mutation (SNP) | VAF 3/23 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60387927, COSV60388411; called by muse, mutect2
- FRAS1 | c.9527A>C p.D3176A | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.871); catalogued as COSV53587652; called by muse, mutect2
- FZD2 | c.286T>C p.Y96H | Missense Mutation (SNP) | VAF 11/111 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59527969; called by muse, mutect2, varscan2
- GAL3ST2 | c.274C>A p.L92M | Missense Mutation (SNP) | VAF 15/74 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV51949358; called by muse, mutect2, varscan2
- GALNT5 | c.212T>C p.I71T | Missense Mutation (SNP) | VAF 12/204 reads (6%) | SIFT tolerated (0.57); PolyPhen benign (0); catalogued as COSV52035692; called by muse, mutect2
- GAPVD1 | c.641A>G p.H214R | Missense Mutation (SNP) | VAF 9/50 reads (18%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.979); catalogued as COSV52919828; called by muse, mutect2, varscan2
- GAPVD1 | c.2476G>A p.A826T (on ENST00000394104; = p.A853T on NM_015635.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 14/98 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.108); catalogued as COSV52919841; called by muse, mutect2, varscan2
- GATA6 | c.343T>C p.F115L | Missense Mutation (SNP) | VAF 7/43 reads (16%) | SIFT deleterious (0.05); PolyPhen benign (0.026); catalogued as COSV52524422; called by muse, mutect2, varscan2
- GATAD2B | c.49A>T p.S17C | Missense Mutation (SNP) | VAF 21/176 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.431); catalogued as COSV64083077; called by muse, mutect2, varscan2
- GEN1 | c.1505A>G p.K502R | Missense Mutation (SNP) | VAF 12/68 reads (18%) | SIFT tolerated (0.35); PolyPhen benign (0.188); catalogued as COSV58055215; called by muse, mutect2, varscan2
- GET4 | c.968C>A p.P323H | Missense Mutation (SNP) | VAF 7/108 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.956); catalogued as COSV56210665; called by muse, mutect2
- GFRA2 | c.1169A>G p.D390G | Missense Mutation (SNP) | VAF 8/48 reads (17%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.73); catalogued as rs1434032976, COSV60777466; called by muse, mutect2, varscan2
- GJB5 | c.214T>C p.S72P | Missense Mutation (SNP) | VAF 9/59 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58355369; called by muse, mutect2, varscan2
- GLS | c.1025C>A p.T342N | Missense Mutation (SNP) | VAF 4/48 reads (8%) | SIFT tolerated (0.08); PolyPhen benign (0.072); catalogued as COSV57839760; called by muse, mutect2
- GLS2 | c.422T>C p.I141T | Missense Mutation (SNP) | VAF 6/54 reads (11%) | SIFT tolerated (0.06); PolyPhen benign (0.202); catalogued as rs960261492, COSV61736644; called by muse, varscan2
- GPR143 | c.520G>A p.A174T | Missense Mutation (SNP) | VAF 11/63 reads (17%) | SIFT tolerated (0.45); PolyPhen benign (0.02); catalogued as rs1322688403, COSV66631888; called by muse, mutect2, varscan2
- GPR149 | c.295G>C p.G99R | Missense Mutation (SNP) | VAF 17/182 reads (9%) | SIFT tolerated (0.14); PolyPhen benign (0.086); catalogued as rs764527641, COSV67665625, COSV67666258, COSV67666659; called by muse, mutect2
- GPR45 | c.187C>T p.P63S | Missense Mutation (SNP) | VAF 19/177 reads (11%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.796); catalogued as COSV51522659, COSV51526953; called by muse, mutect2, varscan2
- GPRASP1 | c.1268T>C p.I423T | Missense Mutation (SNP) | VAF 18/110 reads (16%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as COSV64354725; called by muse, mutect2, varscan2
- GPRASP2 | c.830A>G p.Y277C | Missense Mutation (SNP) | VAF 26/194 reads (13%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as COSV59990187; called by muse, mutect2, varscan2
- GPSM3 | c.158G>A p.R53H | Missense Mutation (SNP) | VAF 7/58 reads (12%) | SIFT tolerated, low confidence (0.55); PolyPhen benign (0); catalogued as rs1270829798, COSV66678539; called by muse, mutect2, varscan2
- GRM4 | c.1586G>A p.R529Q | Missense Mutation (SNP) | VAF 28/92 reads (30%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.956); catalogued as rs201158537, COSV65210342; called by muse, mutect2, varscan2
- GRSF1 | c.473C>A p.P158H | Missense Mutation (SNP) | VAF 4/27 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV54654419; called by muse, mutect2, varscan2
- GUCY1A1 | c.16C>T p.L6F | Missense Mutation (SNP) | VAF 6/50 reads (12%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.017); catalogued as COSV56648908; called by muse, mutect2, varscan2
- GULP1 | c.367C>T p.H123Y | Missense Mutation (SNP) | VAF 14/90 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV63064589; called by muse, mutect2, varscan2
- H2BC11 | c.19T>A p.S7T | Missense Mutation (SNP) | VAF 10/138 reads (7%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0); catalogued as COSV60361645; called by muse, mutect2
- HBS1L | c.430+2T>C p.X144_splice | Splice Site (SNP) | VAF 10/135 reads (7%) | catalogued as COSV59018596; called by muse, mutect2
- HDGFL3 | c.22G>A p.E8K | Missense Mutation (SNP) | VAF 5/22 reads (23%) | SIFT tolerated (0.13); PolyPhen benign (0.043); catalogued as COSV55204250; called by muse, mutect2
- HDLBP | c.1112C>T p.A371V | Missense Mutation (SNP) | VAF 40/257 reads (16%) | SIFT tolerated (0.1); PolyPhen benign (0.29); catalogued as COSV60491804; called by muse, mutect2, varscan2
- HFM1 | c.2702C>T p.A901V | Missense Mutation (SNP) | VAF 4/43 reads (9%) | SIFT tolerated (0.58); PolyPhen benign (0.006); catalogued as COSV54020724; called by muse, mutect2
- HIVEP1 | c.2638G>A p.V880I | Missense Mutation (SNP) | VAF 18/170 reads (11%) | SIFT tolerated (0.12); PolyPhen benign (0.045); catalogued as rs575359353, COSV65098491; called by muse, mutect2, varscan2
- HIVEP1 | c.8119A>G p.S2707G | Missense Mutation (SNP) | VAF 9/92 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV65098505; called by muse, mutect2, varscan2
- HIVEP2 | c.4720A>G p.T1574A | Missense Mutation (SNP) | VAF 17/145 reads (12%) | SIFT tolerated (0.52); PolyPhen benign (0.001); catalogued as COSV50005412; called by muse, mutect2, varscan2
- HK2 | c.557T>C p.V186A | Missense Mutation (SNP) | VAF 15/134 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as COSV51873058; called by muse, mutect2, varscan2
- HLA-DRA | c.317C>T p.P106L | Missense Mutation (SNP) | VAF 23/212 reads (11%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.865); catalogued as rs754838655, COSV66622479; called by muse, mutect2, varscan2
- HLF | c.752A>G p.N251S | Missense Mutation (SNP) | VAF 4/48 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV56828400; called by muse, mutect2
- HMCN1 | c.8468A>G p.K2823R | Missense Mutation (SNP) | VAF 10/106 reads (9%) | SIFT tolerated (0.77); PolyPhen benign (0.005); catalogued as COSV54875146; called by muse, mutect2
- HNF4A | c.280T>C p.Y94H | Missense Mutation (SNP) | VAF 6/38 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV57379359; called by muse, mutect2, varscan2
- HOXB4 | c.748G>A p.A250T | Missense Mutation (SNP) | VAF 5/22 reads (23%) | SIFT tolerated, low confidence (0.41); PolyPhen benign (0.001); catalogued as COSV60177948; called by muse, mutect2
- HS6ST2 | c.1121C>T p.P374L | Missense Mutation (SNP) | VAF 7/52 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0.006); catalogued as COSV63710527, COSV63713383; called by muse, mutect2, varscan2
- HTT | c.3143+2T>C p.X1048_splice | Splice Site (SNP) | VAF 6/94 reads (6%) | catalogued as COSV61857184; called by muse, mutect2
- ICE2 | c.2165A>G p.Y722C | Missense Mutation (SNP) | VAF 6/52 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1443072908, COSV55029591; called by muse, mutect2, varscan2
- IFT172 | c.2366G>A p.R789Q | Missense Mutation (SNP) | VAF 11/106 reads (10%) | SIFT tolerated (0.63); PolyPhen benign (0.003); catalogued as rs148237432; called by muse, mutect2, varscan2
- IQCA1 | c.1489T>C p.S497P | Missense Mutation (SNP) | VAF 4/86 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV54495163; called by muse, mutect2
- IRX2 | c.512G>A p.R171H | Missense Mutation (SNP) | VAF 25/140 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57409553; called by muse, mutect2, varscan2
- ITGA8 | c.2061A>C p.E687D | Missense Mutation (SNP) | VAF 14/111 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV65224190; called by muse, mutect2, varscan2
- ITIH6 | c.2023A>G p.T675A | Missense Mutation (SNP) | VAF 15/100 reads (15%) | SIFT tolerated (0.47); PolyPhen benign (0.003); catalogued as COSV54486252; called by muse, mutect2, varscan2
- JAKMIP2 | c.1601C>A p.A534D | Missense Mutation (SNP) | VAF 139/280 reads (50%) | SIFT deleterious (0.01); PolyPhen benign (0.158); catalogued as COSV54597178, COSV54605070; called by muse, mutect2, varscan2
- JAM2 | c.857G>A p.S286N | Missense Mutation (SNP) | VAF 11/94 reads (12%) | SIFT tolerated (0.09); PolyPhen benign (0.001); catalogued as COSV57255267; called by muse, mutect2, varscan2
- JHY | c.380G>A p.R127H | Missense Mutation (SNP) | VAF 40/295 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as COSV56217831; called by muse, mutect2, varscan2
- JKAMP | c.165T>A p.N55K (on ENST00000554271 / NM_001284201.1; = p.N41K on NM_016475.5 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 12/177 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.109); catalogued as COSV54198323; called by muse, mutect2
- KANK1 | c.3080T>G p.V1027G | Missense Mutation (SNP) | VAF 8/148 reads (5%) | SIFT tolerated (0.38); PolyPhen benign (0.001); catalogued as COSV63209471; called by muse, mutect2
- KAT6A | c.2114A>C p.H705P | Missense Mutation (SNP) | VAF 10/104 reads (10%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.855); catalogued as COSV55902412; called by muse, mutect2, varscan2
- KCNF1 | c.1162G>A p.A388T | Missense Mutation (SNP) | VAF 8/63 reads (13%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.927); catalogued as rs866757061, COSV54461948; called by muse, mutect2, varscan2
- KCNH1 | c.1577A>G p.Y526C (on ENST00000271751 / NM_172362.3; = p.Y499C on NM_002238.4) | Missense Mutation (SNP) | VAF 5/53 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as COSV55068585; called by muse, mutect2
- KCNH5 | c.166G>A p.A56T | Missense Mutation (SNP) | VAF 7/79 reads (9%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as COSV59751616, COSV59757659; called by muse, mutect2, varscan2
- KCNQ2 | c.1439T>C p.V480A (on ENST00000359125 / NM_172107.4; = p.V452A on NM_004518.6) | Missense Mutation (SNP) | VAF 7/104 reads (7%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.575); catalogued as COSV60539769; called by muse, mutect2
- KCNQ3 | c.1749G>T p.K583N | Missense Mutation (SNP) | VAF 17/86 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.046); catalogued as COSV101195781; called by muse, mutect2, varscan2
- KCNT2 | c.3109A>G p.T1037A | Missense Mutation (SNP) | VAF 21/83 reads (25%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as COSV54063237; called by muse, mutect2, varscan2
- KIAA1191 | c.433T>G p.Y145D | Missense Mutation (SNP) | VAF 12/139 reads (9%) | SIFT deleterious (0.04); PolyPhen benign (0.013); catalogued as COSV53798192; called by muse, mutect2
- KIF26A | c.2501A>T p.D834V | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59464369; called by muse, mutect2, varscan2
- KIRREL1 | c.1009del p.L337Sfs*14 | Frame Shift Del (DEL) | VAF 11/100 reads (11%) | catalogued as rs754171400, COSV63285253; called by mutect2, pindel, varscan2
- KLHDC3 | c.961T>G p.F321V | Missense Mutation (SNP) | VAF 6/134 reads (4%) | SIFT tolerated (0.59); PolyPhen benign (0.011); catalogued as COSV55063491; called by muse, mutect2
- KLHL10 | c.829T>C p.S277P | Missense Mutation (SNP) | VAF 30/109 reads (28%) | SIFT tolerated (0.11); PolyPhen benign (0.003); catalogued as rs921448048, COSV53172552; called by muse, mutect2, varscan2
- KLHL28 | c.1654A>C p.T552P | Missense Mutation (SNP) | VAF 10/200 reads (5%) | SIFT tolerated (0.23); PolyPhen benign (0.107); catalogued as COSV61887324; called by muse, mutect2
- KLK8 | c.721G>A p.V241I | Missense Mutation (SNP) | VAF 29/174 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.959); catalogued as rs56296296; called by muse, mutect2, varscan2
- KMT2A | c.6263A>G p.E2088G | Missense Mutation (SNP) | VAF 8/104 reads (8%) | SIFT tolerated (0.12); PolyPhen benign (0.054); catalogued as COSV63281596; called by muse, mutect2
- KRT2 | c.1354G>T p.A452S | Missense Mutation (SNP) | VAF 21/165 reads (13%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.45); catalogued as COSV59008983; called by muse, mutect2, varscan2
- LAS1L | c.1567T>C p.S523P | Missense Mutation (SNP) | VAF 6/126 reads (5%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.642); catalogued as COSV56706283; called by muse, mutect2
- LCN8 | c.253G>A p.V85M (on ENST00000612714 / NM_001345934.1; = p.V62M on NM_178469.3) | Missense Mutation (SNP) | VAF 20/159 reads (13%) | SIFT deleterious (0.05); PolyPhen benign (0.007); catalogued as COSV60209305; called by muse, mutect2, varscan2
- LGR5 | c.44T>C p.L15P | Missense Mutation (SNP) | VAF 12/130 reads (9%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.001); catalogued as COSV57001963; called by muse, mutect2
- LHFPL5 | c.526C>T p.R176C | Missense Mutation (SNP) | VAF 10/83 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs768655651, COSV64177040; called by muse, mutect2, varscan2
- LILRB5 | c.1762del p.L588Wfs*34 (on ENST00000449561 / NM_001081442.3; = p.L587Wfs*34 on NM_006840.5) | Frame Shift Del (DEL) | VAF 18/87 reads (21%) | catalogued as rs775329343; called by mutect2, pindel, varscan2
- LINGO2 | c.1806C>A p.N602K | Missense Mutation (SNP) | VAF 18/122 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.889); catalogued as COSV58056787; called by muse, mutect2, varscan2
- LOXL4 | c.1040T>C p.V347A | Missense Mutation (SNP) | VAF 8/142 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); catalogued as COSV53254933; called by muse, mutect2
- LRIG2 | c.1963C>A p.P655T | Missense Mutation (SNP) | VAF 6/110 reads (5%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.97); catalogued as COSV63160689; called by muse, mutect2
- LRP1B | c.9497G>A p.S3166N | Missense Mutation (SNP) | VAF 11/105 reads (10%) | SIFT tolerated (0.09); PolyPhen benign (0.118); catalogued as COSV67184464; called by muse, mutect2, varscan2
- LRP1B | c.4021A>G p.T1341A | Missense Mutation (SNP) | VAF 27/169 reads (16%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV67184471; called by muse, mutect2, varscan2
- LRRC8B | c.1390A>G p.N464D | Missense Mutation (SNP) | VAF 16/79 reads (20%) | SIFT tolerated (0.18); PolyPhen benign (0.01); catalogued as rs376715317; called by muse, mutect2, varscan2
- LTF | c.968C>T p.A323V | Missense Mutation (SNP) | VAF 8/87 reads (9%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.483); catalogued as COSV51605398; called by muse, mutect2
- LTN1 | c.4498T>C p.S1500P | Missense Mutation (SNP) | VAF 49/249 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.923); catalogued as COSV63732895; called by muse, mutect2, varscan2
- LUC7L3 | c.1165dup p.S389Kfs*2 | Frame Shift Ins (INS) | VAF 14/94 reads (15%) | catalogued as rs1229438198; called by mutect2, varscan2
- LY6G5C | c.622T>C p.Y208H (on ENST00000375863; = p.Y133H on NM_025262.3) | Missense Mutation (SNP) | VAF 16/182 reads (9%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.088); catalogued as rs377069640, COSV65497567; called by muse, mutect2
- MACF1 | c.5771C>T p.S1924L | Missense Mutation (SNP) | VAF 13/85 reads (15%) | catalogued as rs150440643; called by muse, mutect2, varscan2
- MAN2A2 | c.3358T>G p.L1120V | Missense Mutation (SNP) | VAF 28/214 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV64637143; called by muse, mutect2, varscan2
- MARVELD3 | c.707A>G p.Y236C | Missense Mutation (SNP) | VAF 18/226 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51703945; called by muse, mutect2
- MB21D2 | c.1371dup p.L458Tfs*7 | Frame Shift Ins (INS) | VAF 30/190 reads (16%) | catalogued as rs34835215; called by mutect2, varscan2
- MED1 | c.2959G>A p.G987R | Missense Mutation (SNP) | VAF 6/46 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.763); catalogued as rs759693158, COSV56122258; called by mutect2, varscan2
- MED12L | c.3196T>G p.F1066V | Missense Mutation (SNP) | VAF 76/174 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as COSV56367874; called by muse, mutect2, varscan2
- MED22 | c.497T>C p.L166P | Missense Mutation (SNP) | VAF 5/34 reads (15%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.001); catalogued as COSV59297087; called by muse, mutect2, varscan2
- METTL9 | c.766G>T p.E256* | Nonsense Mutation (SNP) | VAF 5/30 reads (17%) | catalogued as COSV51678338; called by muse, mutect2, varscan2
- MFSD6 | c.1778T>C p.L593S | Missense Mutation (SNP) | VAF 17/140 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.772); catalogued as rs1304815131, COSV55620878; called by muse, mutect2, varscan2
- MINK1 | c.3193G>T p.V1065L | Missense Mutation (SNP) | VAF 6/29 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.909); catalogued as COSV99544666; called by muse, mutect2, varscan2
- MIS18BP1 | c.1139del p.N380Ifs*3 | Frame Shift Del (DEL) | VAF 8/70 reads (11%) | catalogued as rs751180035; called by mutect2, varscan2
- MPP6 | c.917del p.K306Rfs*4 | Frame Shift Del (DEL) | VAF 24/199 reads (12%) | catalogued as rs757450051; ClinVar: not provided; called by mutect2, varscan2
- MPV17 | c.224G>A p.R75Q | Missense Mutation (SNP) | VAF 14/78 reads (18%) | SIFT tolerated (0.14); PolyPhen benign (0.413); catalogued as rs763891393, COSV51989273; called by muse, mutect2, varscan2
- MROH2B | c.4114del p.I1372Sfs*5 | Frame Shift Del (DEL) | VAF 10/80 reads (13%) | catalogued as rs756600463; called by mutect2, varscan2
- MTMR3 | c.2086G>A p.A696T | Missense Mutation (SNP) | VAF 11/98 reads (11%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.939); catalogued as COSV60301619; called by muse, mutect2
- MUC4 | c.16216A>G p.N5406D (on ENST00000463781 / NM_018406.7; = p.N1170D on NM_004532.6) | Missense Mutation (SNP) | VAF 12/227 reads (5%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV57764548; called by muse, mutect2
- MVP | c.1341G>T p.Q447H | Missense Mutation (SNP) | VAF 3/24 reads (13%) | SIFT tolerated (0.09); PolyPhen benign (0.235); catalogued as COSV62421312; called by muse, mutect2
- MYH15 | c.40del p.W14Gfs*5 | Frame Shift Del (DEL) | VAF 21/81 reads (26%) | catalogued as rs752868848; called by mutect2, pindel, varscan2
- MYH6 | c.295C>T p.P99S | Missense Mutation (SNP) | VAF 11/56 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.953); catalogued as COSV62447725; called by muse, mutect2, varscan2
- MYH7B | c.1451T>C p.V484A | Missense Mutation (SNP) | VAF 12/150 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV53416327; called by muse, mutect2
- MYO16 | c.2525del p.F842Sfs*17 | Frame Shift Del (DEL) | VAF 10/79 reads (13%) | catalogued as rs761471964; called by mutect2, varscan2
- MYO1D | c.1864C>T p.R622C | Missense Mutation (SNP) | VAF 36/192 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1366755677, COSV59006869; called by muse, mutect2, varscan2
- MYOM2 | c.1561G>A p.E521K | Missense Mutation (SNP) | VAF 9/78 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs754695421, COSV50701878, COSV50719065; called by muse, mutect2, varscan2
- MYPN | c.2737A>G p.M913V | Missense Mutation (SNP) | VAF 4/43 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.293); catalogued as COSV62731440; called by muse, mutect2
- MYPN | c.3205C>T p.R1069C | Missense Mutation (SNP) | VAF 18/170 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs368448794, COSV62731448; called by muse, mutect2, varscan2
- MYT1L | c.2324T>C p.M775T | Missense Mutation (SNP) | VAF 6/88 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.043); catalogued as COSV67707387; called by muse, mutect2
- NCAM2 | c.2411C>T p.P804L | Missense Mutation (SNP) | VAF 7/79 reads (9%) | SIFT tolerated (0.14); PolyPhen benign (0.028); catalogued as COSV53055234, COSV53104559; called by muse, mutect2
- NCOA7 | c.442A>G p.T148A | Missense Mutation (SNP) | VAF 6/42 reads (14%) | SIFT tolerated (0.65); PolyPhen possibly damaging (0.618); catalogued as COSV57652076; called by muse, mutect2, varscan2
- NEFH | c.2512C>T p.P838S | Missense Mutation (SNP) | VAF 7/33 reads (21%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.656); catalogued as rs370229372, COSV60214881; called by muse, mutect2, varscan2
- NEK2 | c.418C>T p.R140W | Missense Mutation (SNP) | VAF 15/136 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs778979955, COSV65355103; called by muse, mutect2, varscan2
- NELL1 | c.2234G>A p.C745Y | Missense Mutation (SNP) | VAF 19/94 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54237515; called by muse, mutect2, varscan2
- NEO1 | c.2823G>A p.W941* | Nonsense Mutation (SNP) | VAF 4/38 reads (11%) | catalogued as COSV56067086; called by muse, mutect2, varscan2
- NEU3 | c.560A>G p.K187R | Missense Mutation (SNP) | VAF 14/147 reads (10%) | SIFT tolerated (0.16); PolyPhen benign (0.05); catalogued as COSV53635553; called by muse, mutect2
- NEXMIF | c.4379A>G p.E1460G | Missense Mutation (SNP) | VAF 7/94 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV50021655, COSV50051299; called by muse, mutect2
- NINL | c.586A>G p.T196A | Missense Mutation (SNP) | VAF 6/41 reads (15%) | SIFT tolerated (0.08); PolyPhen benign (0.027); catalogued as COSV53998330; called by muse, mutect2, varscan2
- NKAPL | c.313C>T p.R105W | Missense Mutation (SNP) | VAF 19/115 reads (17%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as rs1021879879, COSV59196888; called by muse, mutect2, varscan2
- NOLC1 | c.264G>T p.E88D | Missense Mutation (SNP) | VAF 3/46 reads (7%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.007); catalogued as COSV64179864; called by muse, mutect2
- NOS2 | c.1777T>C p.F593L | Missense Mutation (SNP) | VAF 7/38 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.524); catalogued as COSV58221509; called by muse, mutect2, varscan2
- NOTCH4 | c.1706A>G p.Q569R | Missense Mutation (SNP) | VAF 7/62 reads (11%) | SIFT tolerated (0.62); PolyPhen benign (0.062); catalogued as COSV100900490; called by muse, mutect2, varscan2
- NR1D2 | c.1242A>C p.K414N | Missense Mutation (SNP) | VAF 14/169 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.919); catalogued as COSV56990415; called by muse, mutect2
- NRCAM | c.1885G>A p.A629T (on ENST00000379028 / NM_001371124.1; = p.A623T on NM_005010.4 and 21 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 8/62 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.946); catalogued as rs139663718, COSV61030768; called by muse, mutect2, varscan2
- NSMCE3 | c.677A>G p.D226G | Missense Mutation (SNP) | VAF 15/131 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.117); catalogued as COSV54262263; called by muse, mutect2, varscan2
- NTPCR | c.221G>A p.R74H | Missense Mutation (SNP) | VAF 8/52 reads (15%) | SIFT tolerated (0.06); PolyPhen benign (0.012); catalogued as rs748037971, COSV64052130; called by muse, mutect2, varscan2
- NTRK3 | c.622+2T>C p.X208_splice | Splice Site (SNP) | VAF 10/35 reads (29%) | catalogued as COSV58108017; called by muse, mutect2, varscan2
- NUAK1 | c.839G>A p.R280Q | Missense Mutation (SNP) | VAF 8/72 reads (11%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.956); catalogued as rs960012986, COSV54600290; called by muse, mutect2, varscan2
- NUDT18 | c.668C>A p.P223H | Missense Mutation (SNP) | VAF 7/112 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.049); catalogued as COSV57156893; called by muse, mutect2
- NUP210L | c.2072del p.L691Wfs*3 | Frame Shift Del (DEL) | VAF 14/68 reads (21%) | catalogued as rs760869296; called by mutect2, varscan2
- NUTM2G | c.775C>T p.R259W | Missense Mutation (SNP) | VAF 14/100 reads (14%) | SIFT tolerated (0.17); PolyPhen benign (0.209); catalogued as rs374944512; called by muse, mutect2, varscan2
- NXPH2 | c.601G>A p.A201T | Missense Mutation (SNP) | VAF 6/35 reads (17%) | SIFT tolerated (0.55); PolyPhen benign (0.225); catalogued as rs765810849, COSV55639800; called by muse, mutect2, varscan2
- OPA3 | c.482C>T p.A161V | Missense Mutation (SNP) | VAF 11/90 reads (12%) | SIFT deleterious (0.05); PolyPhen benign (0.009); catalogued as rs1276202629, COSV54397963, COSV54398180; called by muse, mutect2, varscan2
- OR13J1 | c.805A>G p.I269V | Missense Mutation (SNP) | VAF 6/66 reads (9%) | SIFT tolerated (0.49); PolyPhen benign (0.014); catalogued as COSV65069301; called by muse, mutect2
- OR1L8 | c.287C>T p.A96V | Missense Mutation (SNP) | VAF 9/89 reads (10%) | SIFT tolerated (0.28); PolyPhen benign (0.013); catalogued as COSV59185684; called by muse, mutect2, varscan2
- OR2H1 | c.923A>G p.D308G | Missense Mutation (SNP) | VAF 5/83 reads (6%) | SIFT tolerated (0.26); PolyPhen benign (0); catalogued as COSV65810123; called by muse, mutect2
- OR4C12 | c.739T>G p.L247V | Missense Mutation (SNP) | VAF 12/44 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.896); catalogued as COSV58859350; called by muse, mutect2, varscan2
- OR4C13 | c.26A>G p.E9G | Missense Mutation (SNP) | VAF 25/82 reads (30%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.887); catalogued as COSV73648609; called by muse, mutect2, varscan2
- OR52D1 | c.92C>T p.A31V | Missense Mutation (SNP) | VAF 19/123 reads (15%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.51); catalogued as rs770208801, COSV59486919; called by muse, mutect2, varscan2
- OR56A3 | c.903A>T p.Q301H | Missense Mutation (SNP) | VAF 51/118 reads (43%) | SIFT tolerated (0.11); PolyPhen benign (0.007); catalogued as COSV61568511; called by muse, mutect2, varscan2
- OR56A4 | c.710T>C p.L237P | Missense Mutation (SNP) | VAF 11/58 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.043); catalogued as COSV58109138; called by muse, mutect2, varscan2
- OR5B2 | c.334T>A p.L112M | Missense Mutation (SNP) | VAF 35/113 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.972); catalogued as COSV100223016, COSV56907457; called by muse, mutect2, varscan2
- OR5K3 | c.599T>G p.F200C | Missense Mutation (SNP) | VAF 7/55 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.886); catalogued as COSV67349645; called by muse, mutect2, varscan2
- OR7E24 | c.887A>G p.Y296C | Missense Mutation (SNP) | VAF 7/64 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV71702117; called by muse, mutect2, varscan2
- OR8K1 | c.388G>A p.V130I | Missense Mutation (SNP) | VAF 10/194 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.621); catalogued as rs1405594221, COSV54401343; called by muse, mutect2
- ORC2 | c.1270A>G p.I424V | Missense Mutation (SNP) | VAF 4/58 reads (7%) | SIFT tolerated (0.07); PolyPhen benign (0.318); catalogued as COSV52236995; called by muse, mutect2
- P2RY10 | c.868del p.C290Afs*34 | Frame Shift Del (DEL) | VAF 40/312 reads (13%) | catalogued as rs34553009; called by mutect2, varscan2
- P2RY4 | c.733C>T p.R245C | Missense Mutation (SNP) | VAF 4/43 reads (9%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.932); catalogued as rs149438352, COSV65736218; called by mutect2, varscan2
- PABPC4 | c.1359A>G p.I453M | Missense Mutation (SNP) | VAF 10/126 reads (8%) | SIFT tolerated (0.41); PolyPhen benign (0.003); catalogued as COSV63293144; called by muse, mutect2
- PAPSS2 | c.70C>A p.H24N | Missense Mutation (SNP) | VAF 11/127 reads (9%) | SIFT tolerated (0.1); PolyPhen benign (0.003); catalogued as COSV63262428; called by muse, mutect2
- PAQR8 | c.166C>T p.R56C | Missense Mutation (SNP) | VAF 14/158 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62441956; called by muse, mutect2
- PCCA | c.689G>A p.R230H | Missense Mutation (SNP) | VAF 7/52 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs747943045, COSV66187867; called by muse, mutect2, varscan2
- PCDH11X | c.2381T>C p.V794A | Missense Mutation (SNP) | VAF 25/137 reads (18%) | SIFT tolerated (0.11); PolyPhen benign (0.02); catalogued as COSV53440758; called by muse, mutect2, varscan2
- PCDH19 | c.3046G>A p.A1016T (on ENST00000373034 / NM_001184880.2; = p.A968T on NM_020766.3) | Missense Mutation (SNP) | VAF 9/84 reads (11%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.99); catalogued as COSV55257182; called by muse, mutect2, varscan2
- PCDHA11 | c.1084G>A p.A362T | Missense Mutation (SNP) | VAF 7/111 reads (6%) | SIFT tolerated, low confidence (0.1); PolyPhen possibly damaging (0.524); catalogued as COSV56475988; called by muse, mutect2
- PCDHA9 | c.1870G>A p.V624M | Missense Mutation (SNP) | VAF 13/155 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.984); catalogued as rs782711616, COSV65323184; called by muse, mutect2
- PCDHAC1 | c.2433+2T>C p.X811_splice | Splice Site (SNP) | VAF 9/236 reads (4%) | catalogued as COSV53836271; called by muse, mutect2
- PCDHB9 | c.1901A>G p.D634G | Missense Mutation (SNP) | VAF 12/143 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.801); catalogued as COSV53381158; called by muse, mutect2
- PCDHGB2 | c.1888C>T p.R630C | Missense Mutation (SNP) | VAF 6/49 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs773499284, COSV99527848; called by muse, mutect2, varscan2
- PCLO | c.15287A>G p.Q5096R | Missense Mutation (SNP) | VAF 6/86 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs933156999, COSV61614840; called by muse, mutect2
- PCLO | c.11095T>C p.Y3699H | Missense Mutation (SNP) | VAF 26/254 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.629); catalogued as rs550715961, COSV61614844; called by muse, mutect2
- PDE3B | c.1028A>T p.Q343L | Missense Mutation (SNP) | VAF 7/53 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV56379467; called by muse, mutect2, varscan2
- PFKFB3 | c.109G>A p.V37I | Missense Mutation (SNP) | VAF 26/256 reads (10%) | PolyPhen benign (0.095); catalogued as rs200349885, COSV57986667; called by muse, mutect2
- PFN3 | c.317C>T p.A106V | Missense Mutation (SNP) | VAF 6/29 reads (21%) | SIFT tolerated (0.54); PolyPhen benign (0.003); catalogued as COSV53689975; called by muse, mutect2
- PGAP1 | c.814G>A p.A272T | Missense Mutation (SNP) | VAF 10/74 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.883); catalogued as COSV61323595; called by muse, mutect2, varscan2
- PHF11 | c.472C>T p.Q158* | Nonsense Mutation (SNP) | VAF 7/55 reads (13%) | catalogued as COSV62896148, COSV62896314; called by muse, mutect2, varscan2
- PHF3 | c.2564C>T p.P855L | Missense Mutation (SNP) | VAF 23/194 reads (12%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.996); catalogued as COSV50313005; called by muse, mutect2
- PIDD1 | c.2116G>A p.V706M | Missense Mutation (SNP) | VAF 14/73 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.636); catalogued as rs762006301, COSV57192199; called by muse, mutect2, varscan2
- PKHD1L1 | c.11488G>A p.V3830I | Missense Mutation (SNP) | VAF 27/176 reads (15%) | SIFT tolerated (0.69); PolyPhen benign (0.001); catalogued as COSV65736559; called by muse, mutect2, varscan2
- PLA2G4F | c.2467G>A p.V823I | Missense Mutation (SNP) | VAF 9/80 reads (11%) | SIFT tolerated (0.62); PolyPhen benign (0.003); catalogued as rs370233019; called by muse, mutect2, varscan2
- PLXNA2 | c.1384G>A p.G462S | Missense Mutation (SNP) | VAF 30/184 reads (16%) | SIFT tolerated (0.81); PolyPhen benign (0.123); catalogued as rs147087031; called by muse, mutect2, varscan2
- PLXNB2 | c.4174A>G p.R1392G | Missense Mutation (SNP) | VAF 11/68 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.825); catalogued as COSV63780000; called by muse, mutect2
- POU6F2 | c.1074A>C p.Q358H | Missense Mutation (SNP) | VAF 14/96 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as rs1191372873, COSV68867250; called by muse, varscan2
- PPFIA3 | c.3031A>C p.I1011L | Missense Mutation (SNP) | VAF 7/37 reads (19%) | SIFT deleterious (0.03); PolyPhen benign (0.087); catalogued as COSV53255190; called by muse, mutect2, varscan2
- PPFIBP1 | c.1942A>G p.T648A (on ENST00000318304 / NM_177444.3; = p.T642A on NM_003622.4) | Missense Mutation (SNP) | VAF 15/143 reads (10%) | SIFT deleterious (0.03); PolyPhen benign (0.21); catalogued as rs1192148477, COSV57287341; called by muse, mutect2
- PPP1R9A | c.1715T>G p.F572C | Missense Mutation (SNP) | VAF 7/49 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV56880628; called by muse, mutect2, varscan2
- PPP3CA | c.1240A>T p.R414* | Nonsense Mutation (SNP) | VAF 12/78 reads (15%) | catalogued as COSV59919239; called by muse, varscan2
- PREPL | c.4C>T p.Q2* | Nonsense Mutation (SNP) | VAF 8/67 reads (12%) | catalogued as COSV53214854; called by muse, mutect2, varscan2
- PREX2 | c.335T>C p.F112S | Missense Mutation (SNP) | VAF 8/65 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.45); catalogued as COSV55749761; called by muse, mutect2
- PRICKLE1 | c.1105G>A p.D369N | Missense Mutation (SNP) | VAF 6/85 reads (7%) | SIFT deleterious (0.02); PolyPhen benign (0.169); catalogued as COSV61541730; called by muse, mutect2
- PRKACG | c.988G>A p.D330N | Missense Mutation (SNP) | VAF 9/115 reads (8%) | SIFT tolerated (0.34); PolyPhen benign (0); catalogued as COSV55240892; called by muse, mutect2
- PROKR2 | c.208G>T p.G70C | Missense Mutation (SNP) | VAF 22/132 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs764674615, COSV54085114; called by muse, mutect2, varscan2
- PRPF3 | c.408G>T p.M136I | Missense Mutation (SNP) | VAF 22/204 reads (11%) | SIFT tolerated (0.44); PolyPhen benign (0); catalogued as COSV61393695; called by muse, mutect2, varscan2
- PRPH | c.592G>A p.V198M | Missense Mutation (SNP) | VAF 5/37 reads (14%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.829); catalogued as rs867804476, COSV57677903; called by muse, mutect2, varscan2
- PSMC5 | c.417G>A p.M139I | Missense Mutation (SNP) | VAF 11/84 reads (13%) | SIFT tolerated (0.18); PolyPhen benign (0.063); catalogued as COSV56737840; called by muse, mutect2, varscan2
- PSMC5 | c.833A>C p.N278T | Missense Mutation (SNP) | VAF 8/160 reads (5%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.951); catalogued as COSV56737842; called by muse, mutect2
- PTPRD | c.5256G>T p.E1752D | Missense Mutation (SNP) | VAF 8/42 reads (19%) | SIFT tolerated (0.06); PolyPhen benign (0.291); catalogued as COSV61926813; called by muse, mutect2
- PTPRN2 | c.463C>A p.L155M | Missense Mutation (SNP) | VAF 18/89 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV67021163; called by muse, mutect2, varscan2
- PUM1 | c.335C>G p.T112S | Missense Mutation (SNP) | VAF 22/124 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.899); catalogued as COSV57081272; called by muse, mutect2, varscan2
- PUM2 | c.396del p.G133Afs*24 | Frame Shift Del (DEL) | VAF 11/65 reads (17%) | catalogued as rs34931937; called by mutect2, pindel, varscan2
- PYGB | c.959G>A p.R320Q | Missense Mutation (SNP) | VAF 14/122 reads (11%) | SIFT tolerated (0.07); PolyPhen benign (0.015); catalogued as rs369254260; called by muse, mutect2, varscan2
- RAB15 | c.160G>T p.G54C | Missense Mutation (SNP) | VAF 8/131 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50824110; called by muse, mutect2
- RABIF | c.269A>C p.K90T | Missense Mutation (SNP) | VAF 6/84 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV66131318; called by muse, mutect2
- RAD18 | c.107T>C p.M36T | Missense Mutation (SNP) | VAF 7/200 reads (4%) | SIFT deleterious (0); PolyPhen benign (0.41); catalogued as COSV53749036; called by muse, mutect2
- RANBP2 | c.6239T>C p.V2080A | Missense Mutation (SNP) | VAF 63/530 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.953); catalogued as COSV51695937; called by muse, mutect2, varscan2
- RASGRF2 | c.1442G>A p.R481H | Missense Mutation (SNP) | VAF 20/114 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.875); catalogued as rs1335545152, COSV54122472; called by muse, mutect2, varscan2
- RAVER2 | c.1892G>A p.C631Y (on ENST00000294428 / NM_001366165.1; = p.C618Y on NM_018211.4) | Missense Mutation (SNP) | VAF 7/69 reads (10%) | SIFT tolerated (0.9); PolyPhen benign (0); catalogued as COSV53804873, COSV99605034; called by muse, mutect2, varscan2
- RBAK | c.2062T>A p.F688I | Missense Mutation (SNP) | VAF 15/146 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV62330751; called by muse, mutect2, varscan2
- RBM27 | c.2448del p.K816Nfs*5 | Frame Shift Del (DEL) | VAF 16/81 reads (20%) | catalogued as rs762006287; called by mutect2, varscan2
- RBM45 | c.1149del p.A384Lfs*7 (on ENST00000616198 / NM_001365579.1; = p.A382Lfs*7 on NM_152945.4 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 16/100 reads (16%) | catalogued as rs749563266; called by mutect2, varscan2
- RBM6 | c.647G>A p.R216K | Missense Mutation (SNP) | VAF 12/84 reads (14%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.602); catalogued as COSV56479525; called by muse, mutect2, varscan2
- RFX3 | c.364G>A p.V122I | Missense Mutation (SNP) | VAF 25/101 reads (25%) | SIFT tolerated (0.19); PolyPhen benign (0.079); catalogued as rs1213429746, COSV56507633; called by muse, mutect2, varscan2
- RGS3 | c.1699C>T p.R567W (on ENST00000350696 / NM_001282923.2; = p.R455W on NM_017790.4) | Missense Mutation (SNP) | VAF 16/128 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs770237002, COSV58276694; called by muse, mutect2, varscan2
- RIC8A | c.1492C>T p.P498S (on ENST00000526104 / NM_001286134.1; = p.P504S on NM_021932.5) | Missense Mutation (SNP) | VAF 5/37 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs763509751, COSV57341985; called by mutect2, varscan2
- RIMKLB | c.470T>G p.V157G | Missense Mutation (SNP) | VAF 27/139 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV55235232; called by muse, mutect2, varscan2
- RMC1 | c.1268A>G p.Y423C | Missense Mutation (SNP) | VAF 5/41 reads (12%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.956); catalogued as COSV52570457; called by muse, mutect2
- RNF169 | c.1250G>A p.S417N | Missense Mutation (SNP) | VAF 9/141 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.037); catalogued as COSV55130352; called by muse, mutect2
- RNF19B | c.1719A>G p.I573M | Missense Mutation (SNP) | VAF 21/125 reads (17%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.708); catalogued as COSV52386692, COSV52389346; called by muse, mutect2, varscan2
- RNF43 | c.1976dup p.P660Sfs*87 | Frame Shift Ins (INS) | VAF 18/144 reads (13%) | catalogued as rs755128667; called by mutect2, varscan2
- RNF6 | c.1718A>C p.N573T | Missense Mutation (SNP) | VAF 19/174 reads (11%) | SIFT tolerated (0.34); PolyPhen benign (0.045); catalogued as COSV60417755; called by muse, mutect2, varscan2
- ROCK1 | c.242T>C p.V81A | Missense Mutation (SNP) | VAF 11/60 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV101296276; called by muse, mutect2, varscan2
- RP1 | c.833T>C p.V278A | Missense Mutation (SNP) | VAF 12/73 reads (16%) | SIFT deleterious (0.04); PolyPhen benign (0.007); catalogued as COSV55109618; called by muse, mutect2, varscan2
- RUSC2 | c.492T>A p.S164R | Missense Mutation (SNP) | VAF 6/74 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.062); catalogued as COSV63427559; called by muse, mutect2
- RXFP3 | c.1322C>T p.A441V | Missense Mutation (SNP) | VAF 10/50 reads (20%) | SIFT tolerated (0.22); PolyPhen benign (0.001); catalogued as rs558444736, COSV57503958, COSV99042320; called by muse, mutect2, varscan2
- SAMD9 | c.3125A>G p.E1042G | Missense Mutation (SNP) | VAF 12/59 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.973); catalogued as COSV66072880; called by muse, mutect2, varscan2
- SCFD1 | c.753C>T p.F251= | Splice Region (SNP) | VAF 3/46 reads (7%) | catalogued as COSV61722112; called by muse, mutect2
- SCN10A | c.4799T>A p.L1600H | Missense Mutation (SNP) | VAF 19/126 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV71860167; called by muse, mutect2, varscan2
- SCN11A | c.4406G>A p.R1469Q | Missense Mutation (SNP) | VAF 7/51 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs1403499986, COSV100182313, COSV56565251; called by muse, mutect2, varscan2
- SCN9A | c.5123T>C p.L1708P (on ENST00000303354; = p.L1697P on NM_002977.3) | Missense Mutation (SNP) | VAF 39/293 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57599454, COSV57620411; called by muse, mutect2, varscan2
- SCYL3 | c.1060C>T p.R354W | Missense Mutation (SNP) | VAF 23/236 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63044388; called by muse, mutect2
- SEL1L2 | c.1034T>C p.L345S | Missense Mutation (SNP) | VAF 10/208 reads (5%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.8); catalogued as COSV53147685; called by muse, mutect2
- SFMBT2 | c.2308G>A p.V770M | Missense Mutation (SNP) | VAF 3/11 reads (27%) | SIFT tolerated (0.11); PolyPhen benign (0.046); catalogued as rs775887528, COSV62804941; called by muse, mutect2
- SFXN2 | c.809T>C p.L270P | Missense Mutation (SNP) | VAF 22/118 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.917); catalogued as COSV64011788; called by muse, mutect2, varscan2
- SGO2 | c.1929del p.G644Vfs*18 | Frame Shift Del (DEL) | VAF 21/154 reads (14%) | catalogued as rs1260834379; called by mutect2, pindel, varscan2
- SGSM2 | c.2018A>C p.D673A (on ENST00000426855 / NM_001098509.2; = p.D718A on NM_014853.3) | Missense Mutation (SNP) | VAF 4/80 reads (5%) | SIFT tolerated (0.2); PolyPhen benign (0.039); catalogued as COSV52155646; called by muse, mutect2
- SH3RF1 | c.2194C>T p.P732S | Missense Mutation (SNP) | VAF 8/80 reads (10%) | SIFT tolerated (1); PolyPhen benign (0.03); catalogued as COSV52918001, COSV52919529; called by muse, mutect2, varscan2
- SI | c.2326C>T p.Q776* | Nonsense Mutation (SNP) | VAF 8/101 reads (8%) | catalogued as COSV52265301; called by muse, mutect2
- SLAMF1 | c.175A>G p.S59G | Missense Mutation (SNP) | VAF 4/66 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.593); catalogued as COSV52497534; called by muse, mutect2
- SLC16A3 | c.791C>T p.A264V | Missense Mutation (SNP) | VAF 20/68 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1250010413, COSV66428995; called by muse, mutect2, varscan2
- SLC35F3 | c.878A>G p.Y293C (on ENST00000366617 / NM_001300845.1; = p.Y362C on NM_173508.4) | Missense Mutation (SNP) | VAF 14/196 reads (7%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.594); catalogued as COSV64018138; called by muse, mutect2
- SLC6A13 | c.1079T>C p.I360T | Missense Mutation (SNP) | VAF 5/47 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58255146; called by muse, mutect2
- SLC6A5 | c.704T>A p.M235K | Missense Mutation (SNP) | VAF 21/87 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.281); catalogued as COSV54223315; called by muse, mutect2, varscan2
- SLCO6A1 | c.194G>A p.R65Q | Missense Mutation (SNP) | VAF 81/226 reads (36%) | SIFT tolerated (0.69); PolyPhen benign (0.005); catalogued as rs1267598371, COSV65805369; called by muse, mutect2, varscan2
- SLIT2 | c.1289A>C p.N430T | Missense Mutation (SNP) | VAF 25/135 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56566796, COSV99062667; called by muse, mutect2, varscan2
- SLIT2 | c.2818T>G p.F940V | Missense Mutation (SNP) | VAF 24/147 reads (16%) | SIFT tolerated (0.6); PolyPhen benign (0.006); catalogued as COSV56559316, COSV99888348; called by muse, mutect2, varscan2
- SLIT3 | c.657C>A p.C219* | Nonsense Mutation (SNP) | VAF 9/70 reads (13%) | catalogued as COSV60591736, COSV60630156; called by muse, mutect2, varscan2
- SMAD9 | c.602C>T p.P201L | Missense Mutation (SNP) | VAF 7/69 reads (10%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.893); catalogued as rs200074185, COSV63203921; called by muse, mutect2, varscan2
- SMARCA4 | c.851G>T p.W284L | Missense Mutation (SNP) | VAF 9/50 reads (18%) | SIFT tolerated (0.41); PolyPhen possibly damaging (0.901); catalogued as COSV60786114; called by muse, mutect2, varscan2
- SORBS1 | c.97G>A p.A33T | Missense Mutation (SNP) | VAF 7/75 reads (9%) | SIFT tolerated, low confidence (0.34); PolyPhen benign (0.023); catalogued as rs747615961, COSV53352948; called by muse, mutect2, varscan2
- SOX5 | c.284A>G p.N95S | Missense Mutation (SNP) | VAF 14/62 reads (23%) | SIFT tolerated (0.52); PolyPhen benign (0.001); catalogued as rs767392175, COSV100505667, COSV58617511; called by muse, mutect2, varscan2
- SOX7 | c.765C>A p.H255Q | Missense Mutation (SNP) | VAF 7/41 reads (17%) | SIFT tolerated (0.06); PolyPhen benign (0.038); catalogued as COSV58730181, COSV58730204; called by muse, mutect2, varscan2
- SPAG17 | c.282dup p.P95Tfs*5 | Frame Shift Ins (INS) | VAF 12/89 reads (13%) | catalogued as rs771461785; called by mutect2, varscan2
- SPAST | c.859A>G p.T287A | Missense Mutation (SNP) | VAF 7/84 reads (8%) | SIFT tolerated (0.64); PolyPhen benign (0); catalogued as COSV59512558; called by muse, mutect2
- SPATA17 | c.500A>G p.Y167C | Missense Mutation (SNP) | VAF 11/132 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV65119231; called by muse, mutect2
- SPATC1 | c.1090C>A p.P364T | Missense Mutation (SNP) | VAF 10/52 reads (19%) | SIFT tolerated (0.17); PolyPhen benign (0.115); catalogued as COSV66298018; called by muse, mutect2
- SPEG | c.3914C>T p.P1305L | Missense Mutation (SNP) | VAF 10/68 reads (15%) | SIFT tolerated (0.07); PolyPhen benign (0.432); catalogued as rs778942315, COSV56662672; called by muse, mutect2, varscan2
- SPIB | c.64G>A p.V22I | Missense Mutation (SNP) | VAF 11/61 reads (18%) | SIFT tolerated (0.4); PolyPhen benign (0); catalogued as rs887253633, COSV54529461; called by muse, mutect2, varscan2
- SPOCK2 | c.991+2T>C p.X331_splice | Splice Site (SNP) | VAF 4/25 reads (16%) | catalogued as COSV58035008; called by muse, mutect2, varscan2
- SPRED1 | c.532T>C p.F178L | Missense Mutation (SNP) | VAF 9/59 reads (15%) | SIFT tolerated (0.4); PolyPhen benign (0.003); catalogued as COSV54434135; called by muse, mutect2, varscan2
- SPRR2A | c.82C>A p.P28T | Missense Mutation (SNP) | VAF 24/204 reads (12%) | SIFT tolerated, low confidence (0.13); PolyPhen probably damaging (0.924); catalogued as COSV101198715; called by muse, mutect2
- SPTA1 | c.3858T>G p.N1286K | Missense Mutation (SNP) | VAF 25/138 reads (18%) | SIFT tolerated (0.73); PolyPhen benign (0.158); catalogued as COSV63748590; called by muse, mutect2, varscan2
- SREBF1 | c.1319C>A p.P440H | Missense Mutation (SNP) | VAF 15/78 reads (19%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.998); catalogued as COSV55414680; called by muse, mutect2, varscan2
- SSH3 | c.1115G>A p.R372H | Missense Mutation (SNP) | VAF 7/119 reads (6%) | SIFT tolerated (0.57); PolyPhen benign (0.37); catalogued as COSV57383246; called by muse, mutect2
- ST3GAL4 | c.608T>C p.I203T (on ENST00000392669 / NM_001254758.1; = p.I199T on NM_006278.3) | Missense Mutation (SNP) | VAF 4/54 reads (7%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.723); catalogued as COSV57105824; called by muse, mutect2
- STARD8 | c.2022T>A p.D674E | Missense Mutation (SNP) | VAF 5/68 reads (7%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as COSV52921363; called by muse, mutect2
- STAT2 | c.1467dup p.K490Qfs*41 | Frame Shift Ins (INS) | VAF 18/108 reads (17%) | catalogued as rs763294380; called by mutect2, varscan2
- STRN | c.1636A>T p.T546S | Missense Mutation (SNP) | VAF 14/117 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0.007); catalogued as COSV55745636; called by muse, mutect2, varscan2
- STYK1 | c.131T>C p.I44T | Missense Mutation (SNP) | VAF 17/188 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV50012207; called by muse, mutect2
- SYCP2 | c.2362del p.M788* | Frame Shift Del (DEL) | VAF 16/68 reads (24%) | catalogued as rs570102997; called by mutect2, varscan2
- SYNDIG1L | c.611G>A p.R204H | Missense Mutation (SNP) | VAF 16/126 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs764119192, COSV59046843; called by muse, mutect2, varscan2
- SYNE1 | c.10046A>C p.Q3349P (on ENST00000367255 / NM_182961.4; = p.Q3356P on NM_033071.3) | Missense Mutation (SNP) | VAF 14/74 reads (19%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.642); catalogued as COSV54901255; called by muse, mutect2, varscan2
- TACC2 | c.8231A>G p.Q2744R (on ENST00000334433; = p.Q822R on NM_006997.4) | Missense Mutation (SNP) | VAF 10/70 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV99586789, COSV99586875; called by muse, varscan2
- TAF1 | c.1877del p.K626Rfs*4 (on ENST00000373790 / NM_138923.4; = p.K647Rfs*4 on NM_004606.5 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 10/66 reads (15%) | catalogued as rs745516519; called by mutect2, varscan2
- TAF7L | c.720G>A p.K240= | Splice Region (SNP) | VAF 28/209 reads (13%) | catalogued as COSV61256236; called by muse, mutect2, varscan2
- TARS3 | c.1866+2T>C p.X622_splice | Splice Site (SNP) | VAF 10/63 reads (16%) | catalogued as COSV60107404; called by muse, mutect2, varscan2
- TBC1D32 | c.2774A>T p.D925V | Missense Mutation (SNP) | VAF 4/13 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.474); catalogued as COSV51535905; called by muse, mutect2, varscan2
- TBX5 | c.88A>G p.S30G | Missense Mutation (SNP) | VAF 8/114 reads (7%) | SIFT tolerated (0.41); PolyPhen benign (0); catalogued as COSV59858323; called by muse, mutect2
- TCEAL1 | c.351A>G p.I117M | Missense Mutation (SNP) | VAF 6/76 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV65460992; called by muse, mutect2
- TECTA | c.2306T>A p.L769H | Missense Mutation (SNP) | VAF 18/80 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.695); catalogued as COSV50687738, COSV50695327; called by muse, mutect2, varscan2
- TET1 | c.3735G>T p.Q1245H | Missense Mutation (SNP) | VAF 14/90 reads (16%) | SIFT tolerated (0.73); PolyPhen benign (0); catalogued as COSV65381822; called by muse, varscan2
- TEX15 | c.7148T>G p.L2383* (on ENST00000256246; = p.L2766* on NM_001350162.2) | Nonsense Mutation (SNP) | VAF 21/171 reads (12%) | catalogued as COSV56341268; called by muse, mutect2, varscan2
- TG | c.4907A>G p.N1636S | Missense Mutation (SNP) | VAF 12/162 reads (7%) | SIFT tolerated (0.22); PolyPhen benign (0.061); catalogued as rs758183389, COSV55064524; called by muse, mutect2
- THBS3 | c.1306C>T p.R436C | Missense Mutation (SNP) | VAF 21/146 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs772718514, COSV64248425; called by muse, mutect2, varscan2
- THG1L | c.890A>G p.D297G | Missense Mutation (SNP) | VAF 47/147 reads (32%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.129); catalogued as rs1253867223, COSV51452199; called by muse, mutect2, varscan2
- THSD1 | c.1435T>C p.S479P | Missense Mutation (SNP) | VAF 4/69 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.649); catalogued as COSV51626358; called by muse, mutect2
- TJP1 | c.2153A>G p.Y718C | Missense Mutation (SNP) | VAF 19/123 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs774071639, COSV62039175; called by muse, mutect2, varscan2
- TJP3 | c.1307A>G p.N436S | Missense Mutation (SNP) | VAF 11/168 reads (7%) | SIFT tolerated (0.13); PolyPhen benign (0.007); catalogued as COSV53660719; called by muse, mutect2
- TKT | c.73A>G p.S25G | Missense Mutation (SNP) | VAF 9/37 reads (24%) | SIFT tolerated (0.16); PolyPhen benign (0.006); catalogued as rs782431137, COSV56244317; called by muse, mutect2, varscan2
- TLR4 | c.1316A>T p.E439V (on ENST00000355622 / NM_138554.5; = p.E399V on NM_003266.4) | Missense Mutation (SNP) | VAF 31/118 reads (26%) | SIFT tolerated (0.21); PolyPhen benign (0.027); catalogued as COSV62922373, COSV62923773, COSV62924192; called by muse, mutect2, varscan2
- TMEFF2 | c.928G>A p.V310I | Missense Mutation (SNP) | VAF 10/81 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs763546804, COSV55827681; called by muse, mutect2, varscan2
- TMEM200B | c.641G>A p.R214H | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT deleterious (0.04); PolyPhen benign (0.049); catalogued as rs1362692869, COSV58040457; called by muse, mutect2, varscan2
- TMEM209 | c.656A>G p.Y219C | Missense Mutation (SNP) | VAF 5/69 reads (7%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.714); catalogued as rs1029687309, COSV61021534; called by muse, mutect2
- TMEM43 | c.440A>G p.Y147C | Missense Mutation (SNP) | VAF 8/63 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60145217; called by muse, mutect2, varscan2
- TMF1 | c.2633T>C p.V878A | Missense Mutation (SNP) | VAF 6/63 reads (10%) | SIFT tolerated (0.86); PolyPhen benign (0); catalogued as COSV68373353; called by muse, mutect2
- TNN | c.2566A>G p.R856G | Missense Mutation (SNP) | VAF 8/66 reads (12%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.928); catalogued as COSV53421316; called by muse, mutect2, varscan2
- TNRC18 | c.6835C>A p.L2279I | Missense Mutation (SNP) | VAF 4/55 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV60306058; called by muse, mutect2
- TOX2 | c.239del p.P80Rfs*2 (on ENST00000358131 / NM_001098798.2; = p.P29Rfs*2 on NM_032883.3) | Frame Shift Del (DEL) | VAF 11/108 reads (10%) | catalogued as COSV100364910; called by mutect2, pindel, varscan2
- TPRG1L | c.757T>C p.S253P | Missense Mutation (SNP) | VAF 8/42 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV54559946; called by muse, mutect2, varscan2
- TRIM37 | c.124C>T p.R42C | Missense Mutation (SNP) | VAF 34/85 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.577); catalogued as rs868397103, COSV51881208; called by muse, mutect2, varscan2
- TRPC5 | c.2428G>T p.G810W | Missense Mutation (SNP) | VAF 41/232 reads (18%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.161); catalogued as COSV53283521; called by muse, mutect2, varscan2
- TSHZ2 | c.593A>G p.Y198C | Missense Mutation (SNP) | VAF 6/66 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61586690; called by muse, mutect2
- TSNAX | c.665G>A p.R222H | Missense Mutation (SNP) | VAF 13/112 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as rs762657262, COSV64145665, COSV64147027, COSV64147189; called by muse, mutect2, varscan2
- TTLL4 | c.3236T>C p.V1079A | Missense Mutation (SNP) | VAF 39/348 reads (11%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV51434829; called by muse, mutect2, varscan2
- TTN | c.96346A>C p.S32116R (on ENST00000591111; = p.S24692R on NM_003319.4) | Missense Mutation (SNP) | VAF 22/147 reads (15%) | PolyPhen benign (0.014); catalogued as COSV59875144; called by muse, mutect2, varscan2
- TTN | c.63484T>G p.F21162V (on ENST00000591111; = p.F13738V on NM_003319.4) | Missense Mutation (SNP) | VAF 14/108 reads (13%) | PolyPhen benign (0.085); catalogued as COSV59875180; called by muse, mutect2, varscan2
- TTN | c.50334G>C p.K16778N (on ENST00000591111; = p.K9354N on NM_003319.4) | Missense Mutation (SNP) | VAF 13/160 reads (8%) | PolyPhen possibly damaging (0.55); catalogued as COSV100629519, COSV59875213; called by muse, mutect2
- TUBB4B | c.877A>G p.M293V | Missense Mutation (SNP) | VAF 18/102 reads (18%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.021); catalogued as COSV61115423; called by muse, mutect2, varscan2
- UBE2V2 | c.220C>A p.P74T | Missense Mutation (SNP) | VAF 6/88 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV72878728, COSV72878760; called by muse, mutect2
- UBN2 | c.3196T>A p.S1066T | Missense Mutation (SNP) | VAF 10/130 reads (8%) | SIFT tolerated, low confidence (0.38); PolyPhen benign (0.108); catalogued as COSV56027435; called by muse, mutect2
- UGT2B28 | c.1540T>G p.F514V | Missense Mutation (SNP) | VAF 6/86 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.367); catalogued as COSV59430461; called by muse, mutect2
- UROC1 | c.920del p.K307Rfs*77 | Frame Shift Del (DEL) | VAF 32/238 reads (13%) | catalogued as rs754361807; called by mutect2, varscan2
- USP54 | c.3549G>C p.W1183C | Missense Mutation (SNP) | VAF 14/300 reads (5%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.003); catalogued as COSV60439549; called by muse, mutect2
- USPL1 | c.594A>C p.R198S | Missense Mutation (SNP) | VAF 20/157 reads (13%) | SIFT tolerated (0.73); PolyPhen benign (0); catalogued as COSV54998437; called by muse, mutect2, varscan2
- USPL1 | c.2426G>A p.S809N | Missense Mutation (SNP) | VAF 6/78 reads (8%) | SIFT tolerated (0.81); PolyPhen benign (0); catalogued as COSV54998445; called by muse, mutect2
- UTP18 | c.621T>A p.D207E | Missense Mutation (SNP) | VAF 7/61 reads (11%) | SIFT tolerated (0.54); PolyPhen benign (0.017); catalogued as COSV56582166; called by muse, mutect2, varscan2
- UTRN | c.9013C>A p.L3005I | Missense Mutation (SNP) | VAF 11/84 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.366); catalogued as COSV62303515; called by muse, mutect2, varscan2
- VENTX | c.268C>T p.R90W | Missense Mutation (SNP) | VAF 10/57 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.895); catalogued as rs748299514, COSV58083989; called by muse, mutect2, varscan2
- VPS16 | c.704C>T p.A235V | Missense Mutation (SNP) | VAF 14/194 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV66791794; called by muse, mutect2
- VPS50 | c.2165C>T p.T722M | Missense Mutation (SNP) | VAF 14/82 reads (17%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.635); catalogued as rs376216197; called by muse, mutect2
- WDFY3 | c.7175A>G p.N2392S | Missense Mutation (SNP) | VAF 40/298 reads (13%) | SIFT tolerated (0.44); PolyPhen benign (0); catalogued as COSV55692894; called by muse, mutect2, varscan2
- WDR11 | c.755A>G p.Y252C | Missense Mutation (SNP) | VAF 16/135 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV54785219; called by muse, mutect2, varscan2
- WDR36 | c.584A>G p.Y195C | Missense Mutation (SNP) | VAF 4/15 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as COSV72411019; called by muse, mutect2
- WDR45B | c.433T>C p.C145R | Missense Mutation (SNP) | VAF 12/40 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV66407748; called by muse, mutect2, varscan2
- WDR49 | c.520T>C p.F174L (on ENST00000308378 / NM_001366158.1; = p.F515L on NM_001348951.2 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 24/103 reads (23%) | SIFT tolerated (0.08); PolyPhen benign (0.123); catalogued as COSV57701699; called by muse, mutect2, varscan2
- WDR70 | c.890G>A p.G297E | Missense Mutation (SNP) | VAF 9/85 reads (11%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV54265780; called by muse, mutect2, varscan2
- WHRN | c.448G>A p.E150K | Missense Mutation (SNP) | VAF 15/116 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.491); catalogued as COSV54326761, COSV54333154; called by muse, mutect2, varscan2
- XIRP2 | c.9008G>A p.R3003H (on ENST00000628543; = p.R3178H on NM_152381.6) | Missense Mutation (SNP) | VAF 20/126 reads (16%) | SIFT tolerated (0.09); PolyPhen benign (0.116); catalogued as rs375622239, COSV54697110; called by muse, mutect2, varscan2
- XPR1 | c.1631A>G p.N544S | Missense Mutation (SNP) | VAF 26/133 reads (20%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.733); catalogued as rs1369181569, COSV62554355; called by muse, mutect2, varscan2
- XXYLT1 | c.985G>A p.G329R | Missense Mutation (SNP) | VAF 14/93 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs772589347, COSV100118500, COSV59980810; called by muse, mutect2, varscan2
- ZBTB38 | c.2981G>A p.G994E | Missense Mutation (SNP) | VAF 10/33 reads (30%) | SIFT tolerated (0.91); PolyPhen benign (0.051); catalogued as rs953009870, COSV58539866; called by muse, mutect2, varscan2
- ZBTB39 | c.1980G>A p.M660I | Missense Mutation (SNP) | VAF 8/112 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV55627733; called by muse, mutect2
- ZFHX3 | c.466G>A p.A156T | Missense Mutation (SNP) | VAF 9/49 reads (18%) | SIFT tolerated (0.67); PolyPhen benign (0.392); catalogued as rs769010742, COSV51707324; called by muse, mutect2, varscan2
- ZKSCAN7 | c.270G>T p.K90N | Missense Mutation (SNP) | VAF 17/79 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56271579; called by muse, mutect2, varscan2
- ZNF180 | c.1175G>A p.R392Q | Missense Mutation (SNP) | VAF 14/80 reads (18%) | SIFT tolerated (0.75); PolyPhen possibly damaging (0.907); catalogued as rs765744565, COSV55419455; called by muse, mutect2, varscan2
- ZNF184 | c.811A>T p.I271F | Missense Mutation (SNP) | VAF 18/131 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.929); catalogued as COSV53003091; called by muse, mutect2, varscan2
- ZNF264 | c.1861A>C p.T621P | Missense Mutation (SNP) | VAF 11/104 reads (11%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.133); catalogued as COSV54040563, COSV54042078; called by muse, mutect2, varscan2
- ZNF37A | c.790A>G p.T264A | Missense Mutation (SNP) | VAF 13/179 reads (7%) | SIFT tolerated (0.09); PolyPhen benign (0.031); catalogued as COSV61072434; called by muse, mutect2
- ZNF398 | c.508A>G p.N170D | Missense Mutation (SNP) | VAF 6/85 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV60064472; called by muse, mutect2
- ZNF468 | c.696del p.K232Nfs*4 | Frame Shift Del (DEL) | VAF 13/88 reads (15%) | catalogued as COSV54697628; called by mutect2, pindel, varscan2
- ZNF490 | c.889G>A p.E297K | Missense Mutation (SNP) | VAF 10/78 reads (13%) | SIFT tolerated (0.12); PolyPhen benign (0.27); catalogued as rs372080877; called by muse, mutect2, varscan2
- ZNF532 | c.3077C>T p.T1026M | Missense Mutation (SNP) | VAF 15/155 reads (10%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.877); catalogued as rs144779931; called by muse, mutect2, varscan2
- ZNF544 | c.56T>C p.V19A | Missense Mutation (SNP) | VAF 42/221 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV54133998; called by muse, mutect2, varscan2
- ZNF599 | c.373G>A p.E125K | Missense Mutation (SNP) | VAF 25/151 reads (17%) | SIFT tolerated (0.11); PolyPhen benign (0.01); catalogued as COSV61395453; called by muse, mutect2, varscan2
- ZNF883 | c.705A>C p.K235N | Missense Mutation (SNP) | VAF 4/52 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); catalogued as COSV71308864, COSV71309211; called by muse, mutect2
- ZNF98 | c.173A>C p.K58T | Missense Mutation (SNP) | VAF 17/94 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.178); catalogued as COSV100757567, COSV63334161; called by muse, mutect2, varscan2
- ZW10 | c.561G>T p.W187C | Missense Mutation (SNP) | VAF 9/71 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52314586; called by muse, mutect2, varscan2
- AC011462.1 | c.187dup p.E63Gfs*6 | Frame Shift Ins (INS) | VAF 8/66 reads (12%) | called by mutect2, pindel
- ADAM33 | c.1202del p.G401Afs*68 | Frame Shift Del (DEL) | VAF 8/49 reads (16%) | called by mutect2, pindel, varscan2
- AHCTF1 | c.6505del p.I2169* (on ENST00000366508; = p.I2143* on NM_015446.5) | Frame Shift Del (DEL) | VAF 7/42 reads (17%) | called by mutect2, pindel, varscan2
- ANLN | c.1428del p.K476Nfs*13 | Frame Shift Del (DEL) | VAF 21/230 reads (9%) | called by mutect2, pindel, varscan2
- ARID1A | c.3216del p.K1072Nfs*21 | Frame Shift Del (DEL) | VAF 8/50 reads (16%) | called by mutect2, pindel, varscan2
- ATRX | c.3904del p.R1302Efs*44 | Frame Shift Del (DEL) | VAF 18/132 reads (14%) | called by mutect2, pindel, varscan2
- C7orf26 | c.1238del p.P413Rfs*29 | Frame Shift Del (DEL) | VAF 10/57 reads (18%) | called by mutect2, pindel, varscan2
- CEP250 | c.2653del p.M885Wfs*5 | Frame Shift Del (DEL) | VAF 8/87 reads (9%) | called by mutect2, pindel
- CEP72 | c.727T>C p.Y243H | Missense Mutation (SNP) | VAF 8/45 reads (18%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- CEP85L | c.1996_1997del p.Q666Efs*8 | Frame Shift Del (DEL) | VAF 7/60 reads (12%) | called by mutect2, varscan2
- CHD7 | c.3059dup p.L1020Ffs*33 | Frame Shift Ins (INS) | VAF 28/222 reads (13%) | called by mutect2, pindel, varscan2
- COL9A1 | c.2403dup p.G802Rfs*21 | Frame Shift Ins (INS) | VAF 14/78 reads (18%) | called by mutect2, pindel, varscan2
- CSF1R | c.608del p.P203Qfs*3 | Frame Shift Del (DEL) | VAF 11/47 reads (23%) | called by mutect2, pindel
- DOCK11 | c.2956del p.R986Efs*20 | Frame Shift Del (DEL) | VAF 12/107 reads (11%) | called by mutect2, pindel, varscan2
- ERICH6 | c.847del p.S283Lfs*22 | Frame Shift Del (DEL) | VAF 18/154 reads (12%) | called by mutect2, pindel
- EXOSC8 | c.485del p.N162Mfs*9 | Frame Shift Del (DEL) | VAF 10/51 reads (20%) | called by mutect2, pindel, varscan2
- FAM207A | c.180del p.S61Afs*11 | Frame Shift Del (DEL) | VAF 6/72 reads (8%) | called by mutect2, pindel
- FANCI | c.1622del p.L541Cfs*4 | Frame Shift Del (DEL) | VAF 24/134 reads (18%) | called by mutect2, pindel, varscan2
- FOXD4L4 | c.942G>A p.W314* | Nonsense Mutation (SNP) | VAF 15/249 reads (6%) | called by muse, mutect2
- GCNA | c.1959dup p.G654Wfs*50 | Frame Shift Ins (INS) | VAF 4/22 reads (18%) | called by mutect2, pindel
- GDF10 | c.859dup p.R287Pfs*22 | Frame Shift Ins (INS) | VAF 6/18 reads (33%) | called by mutect2, varscan2
- HEATR5A | c.5018del p.K1673Rfs*24 | Frame Shift Del (DEL) | VAF 6/54 reads (11%) | called by mutect2, varscan2
- HECW1 | c.726del p.A243Pfs*14 | Frame Shift Del (DEL) | VAF 7/81 reads (9%) | called by mutect2, pindel
- KIAA1841 | c.761del p.N254Ifs*2 | Frame Shift Del (DEL) | VAF 11/86 reads (13%) | called by mutect2, pindel, varscan2
- KIF21A | c.1672del p.R558Gfs*42 (on ENST00000361418 / NM_001378440.1; = p.S558Vfs*29 on NM_017641.4 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 8/55 reads (15%) | called by mutect2, pindel, varscan2
- KMO | c.1259del p.K420Rfs*2 | Frame Shift Del (DEL) | VAF 27/139 reads (19%) | called by mutect2, pindel, varscan2
- KYNU | c.1080dup p.S361Ifs*15 | Frame Shift Ins (INS) | VAF 8/84 reads (10%) | called by mutect2, pindel, varscan2
- LAMC1 | c.1094del p.G365Afs*42 | Frame Shift Del (DEL) | VAF 30/193 reads (16%) | called by mutect2, pindel, varscan2
- LCT | c.2728G>A p.G910S | Missense Mutation (SNP) | VAF 12/103 reads (12%) | SIFT tolerated (0.14); PolyPhen probably damaging (1); called by muse, mutect2
- LEF1 | c.1130_1132del p.K377del | In Frame Del (DEL) | VAF 8/61 reads (13%) | called by pindel, varscan2
- MAP2 | c.943dup p.S315Kfs*18 | Frame Shift Ins (INS) | VAF 17/118 reads (14%) | called by mutect2, pindel, varscan2
- MAPRE3 | c.543del p.C182Afs*31 | Frame Shift Del (DEL) | VAF 12/70 reads (17%) | called by mutect2, varscan2
- OR10G9 | c.694G>T p.G232W | Missense Mutation (SNP) | VAF 10/114 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- PBRM1 | c.773dup p.N258Kfs*6 | Frame Shift Ins (INS) | VAF 20/118 reads (17%) | called by mutect2, pindel, varscan2
- PEX6 | c.1149dup p.K384* | Frame Shift Ins (INS) | VAF 10/83 reads (12%) | called by mutect2, pindel
- PLEKHA5 | c.453del p.V152Ffs*33 | Frame Shift Del (DEL) | VAF 10/71 reads (14%) | called by mutect2, pindel, varscan2
- PNPLA7 | c.1369_1371del p.K457del | In Frame Del (DEL) | VAF 8/75 reads (11%) | called by pindel, varscan2
- PSAP | c.1277del p.N426Tfs*37 | Frame Shift Del (DEL) | VAF 11/97 reads (11%) | called by mutect2, pindel, varscan2
- RAI14 | c.1355_1356del p.R452Kfs*21 | Frame Shift Del (DEL) | VAF 12/94 reads (13%) | called by pindel, varscan2
- RERE | c.146del p.N49Ifs*46 | Frame Shift Del (DEL) | VAF 43/371 reads (12%) | called by mutect2, pindel, varscan2
- RET | c.2849del p.N950Tfs*15 | Frame Shift Del (DEL) | VAF 16/166 reads (10%) | called by mutect2, pindel
- REXO1 | c.870_872del p.E290del | In Frame Del (DEL) | VAF 6/39 reads (15%) | called by pindel, varscan2
- SERPINI1 | c.248del p.N83Mfs*8 | Frame Shift Del (DEL) | VAF 27/154 reads (18%) | called by mutect2, pindel, varscan2
- SETBP1 | c.1261del p.R421Dfs*23 | Frame Shift Del (DEL) | VAF 10/41 reads (24%) | called by mutect2, pindel, varscan2
- SFI1 | c.2453_2454del p.R818Tfs*138 (on ENST00000400288 / NM_001007467.3; = p.R787Tfs*138 on NM_014775.4) | Frame Shift Del (DEL) | VAF 6/48 reads (13%) | called by pindel, varscan2
- SGSM2 | c.2442del p.N815Tfs*50 (on ENST00000426855 / NM_001098509.2; = p.N860Tfs*50 on NM_014853.3) | Frame Shift Del (DEL) | VAF 13/62 reads (21%) | called by mutect2, pindel, varscan2
- SHOC1 | c.4005dup p.C1336Mfs*5 | Frame Shift Ins (INS) | VAF 20/123 reads (16%) | called by mutect2, pindel, varscan2
- TEAD3 | c.872del p.P291Lfs*37 | Frame Shift Del (DEL) | VAF 9/64 reads (14%) | called by mutect2, pindel, varscan2
- TET3 | c.1052del p.N351Tfs*190 | Frame Shift Del (DEL) | VAF 6/64 reads (9%) | called by pindel, varscan2
- TOP2B | c.102del p.E35Kfs*44 (on ENST00000264331 / NM_001330700.2; = p.E30Kfs*44 on NM_001068.3) | Frame Shift Del (DEL) | VAF 7/34 reads (21%) | called by mutect2, pindel, varscan2
- TRAF6 | c.419T>C p.L140S | Missense Mutation (SNP) | VAF 4/89 reads (4%) | SIFT tolerated (0.75); PolyPhen benign (0); called by muse, mutect2
- TTN | c.98249dup p.P32751Tfs*17 (on ENST00000591111; = p.P25327Tfs*17 on NM_003319.4) | Frame Shift Ins (INS) | VAF 8/61 reads (13%) | called by mutect2, pindel, varscan2
- ULK2 | c.834del p.K278Nfs*130 | Frame Shift Del (DEL) | VAF 9/95 reads (9%) | called by mutect2, pindel, varscan2
- UNC13C | c.1709del p.F570Sfs*37 | Frame Shift Del (DEL) | VAF 4/26 reads (15%) | called by mutect2, pindel
- USP34 | c.2363dup p.N788Kfs*4 | Frame Shift Ins (INS) | VAF 12/71 reads (17%) | called by mutect2, varscan2
- YBX2 | c.677del p.P226Hfs*22 | Frame Shift Del (DEL) | VAF 34/217 reads (16%) | called by mutect2, varscan2
- ZNF221 | c.1512del p.K504Nfs*75 | Frame Shift Del (DEL) | VAF 18/103 reads (17%) | called by mutect2, pindel, varscan2
- ZNF521 | c.115del p.E39Rfs*21 | Frame Shift Del (DEL) | VAF 19/91 reads (21%) | called by mutect2, pindel, varscan2
- ZPBP | c.780del p.F260Lfs*7 | Frame Shift Del (DEL) | VAF 12/115 reads (10%) | called by mutect2, pindel, varscan2
- ABCA1 | c.1936C>T p.L646= | Silent (SNP) | VAF 10/54 reads (19%) | catalogued as COSV66063538; called by muse, mutect2, varscan2
- ABCE1 | c.60A>G p.K20= | Silent (SNP) | VAF 14/65 reads (22%) | catalogued as COSV56846118; called by muse, mutect2, varscan2
- AFDN | c.3072A>G p.A1024= | Silent (SNP) | VAF 6/62 reads (10%) | catalogued as COSV60036803; called by muse, mutect2, varscan2
- AHR | c.787T>C p.L263= | Silent (SNP) | VAF 12/107 reads (11%) | catalogued as COSV54121485; called by muse, mutect2, varscan2
- APC | c.2766T>C p.L922= | Silent (SNP) | VAF 10/41 reads (24%) | catalogued as COSV57323252; called by muse, mutect2, varscan2
- ASB3 | c.108C>G p.V36= | Silent (SNP) | VAF 25/194 reads (13%) | catalogued as COSV54857587; called by muse, mutect2, varscan2
- ATXN10 | c.684G>A p.P228= | Silent (SNP) | VAF 28/155 reads (18%) | catalogued as rs760818193, COSV53293373; called by muse, mutect2, varscan2
- B3GALT5 | c.678G>A p.A226= | Silent (SNP) | VAF 26/96 reads (27%) | catalogued as rs1453117170, COSV58197798; called by muse, mutect2, varscan2
- BAG3 | c.1056C>A p.S352= | Silent (SNP) | VAF 22/198 reads (11%) | catalogued as COSV64841590; called by muse, mutect2, varscan2
- BCAR3 | c.2313T>C p.D771= | Silent (SNP) | VAF 4/70 reads (6%) | called by muse, mutect2
- BEND7 | c.70C>A p.R24= | Silent (SNP) | VAF 15/254 reads (6%) | catalogued as COSV61987171, COSV61991733; called by muse, mutect2
- C16orf71 | c.186T>C p.I62= | Silent (SNP) | VAF 5/72 reads (7%) | catalogued as COSV58507111; called by muse, mutect2
- C4orf17 | c.777A>C p.P259= | Silent (SNP) | VAF 35/106 reads (33%) | catalogued as COSV58511238; called by muse, mutect2, varscan2
- CAPS2 | c.1047T>C p.S349= | Silent (SNP) | VAF 8/61 reads (13%) | catalogued as COSV60823896; called by muse, mutect2, varscan2
- CARD6 | c.1917A>G p.R639= | Silent (SNP) | VAF 42/272 reads (15%) | catalogued as COSV54564100; called by muse, mutect2, varscan2
- CCDC6 | c.841T>C p.L281= | Silent (SNP) | VAF 17/125 reads (14%) | catalogued as COSV54054406; called by muse, mutect2, varscan2
- CEBPZ | c.1599A>G p.V533= | Silent (SNP) | VAF 23/159 reads (14%) | catalogued as COSV50016876; called by muse, mutect2, varscan2
- CHD3 | c.4545G>A p.P1515= | Silent (SNP) | VAF 24/155 reads (15%) | catalogued as rs779331791, COSV57872298; called by muse, mutect2, varscan2
- CHTOP | c.18G>A p.A6= | Silent (SNP) | VAF 7/68 reads (10%) | catalogued as rs553593380, COSV52679569, COSV52680113; called by mutect2, varscan2
- CKAP5 | c.1695C>T p.G565= | Silent (SNP) | VAF 12/80 reads (15%) | catalogued as rs756495835, COSV56363753; called by muse, mutect2, varscan2
- CLIP4 | c.1810T>C p.L604= | Silent (SNP) | VAF 10/85 reads (12%) | catalogued as COSV60747332; called by muse, mutect2, varscan2
- CLK2 | c.1401G>A p.R467= (on ENST00000368361 / NM_001294339.2; = p.R466= on NM_003993.4) | Silent (SNP) | VAF 6/89 reads (7%) | catalogued as COSV56943603; called by muse, mutect2
- CLSTN2 | c.240C>T p.I80= | Silent (SNP) | VAF 36/250 reads (14%) | catalogued as COSV71717982, COSV71726045; called by muse, mutect2, varscan2
- CPPED1 | c.762T>C p.G254= | Silent (SNP) | VAF 6/53 reads (11%) | catalogued as COSV55495511; called by mutect2, varscan2
- CPSF1 | c.1935C>A p.P645= | Silent (SNP) | VAF 8/59 reads (14%) | catalogued as COSV58232074; called by muse, mutect2, varscan2
- CRYL1 | c.954C>A p.P318= | Silent (SNP) | VAF 10/144 reads (7%) | catalogued as COSV53416063; called by muse, mutect2
- CSMD2 | c.9945C>T p.G3315= | Silent (SNP) | VAF 9/56 reads (16%) | catalogued as rs755183571, COSV53876779; called by muse, mutect2
- CTTN | c.120T>C p.G40= | Silent (SNP) | VAF 24/152 reads (16%) | catalogued as COSV57230083; called by muse, mutect2, varscan2
- CUX2 | c.2340C>T p.G780= | Silent (SNP) | VAF 18/98 reads (18%) | catalogued as COSV55623931; called by muse, mutect2, varscan2
- DACT1 | c.2163T>C p.A721= | Silent (SNP) | VAF 7/76 reads (9%) | catalogued as COSV60019306; called by muse, mutect2
- DAGLA | c.447G>A p.V149= | Silent (SNP) | VAF 21/157 reads (13%) | catalogued as COSV57193808; called by muse, mutect2, varscan2
- DCX | c.510C>G p.A170= | Silent (SNP) | VAF 20/83 reads (24%) | catalogued as COSV57565699; called by muse, mutect2, varscan2
- DENND4B | c.1038C>T p.H346= | Silent (SNP) | VAF 8/126 reads (6%) | catalogued as rs1276298244, COSV63407071; called by muse, mutect2
- DLGAP3 | c.567G>A p.A189= | Silent (SNP) | VAF 11/44 reads (25%) | catalogued as rs1253025258, COSV52391229; called by muse, mutect2, varscan2
- DNAH7 | c.1908C>T p.L636= | Silent (SNP) | VAF 17/126 reads (13%) | catalogued as rs371183223; called by muse, mutect2, varscan2
- DNMT1 | c.3996C>T p.H1332= | Silent (SNP) | VAF 10/104 reads (10%) | catalogued as rs751126457, COSV61576387; called by muse, mutect2
- DOP1A | c.4932G>A p.V1644= | Silent (SNP) | VAF 12/97 reads (12%) | catalogued as rs1359485392, COSV52706634; called by muse, varscan2
- DRC1 | c.1584G>T p.L528= | Silent (SNP) | VAF 4/28 reads (14%) | catalogued as COSV56528732; called by muse, mutect2, varscan2
- EEF1AKMT4-ECE2 | c.2553C>T p.R851= | Silent (SNP) | VAF 23/115 reads (20%) | catalogued as rs745688760, COSV62566583; called by muse, mutect2, varscan2
- EHBP1 | c.873T>C p.T291= | Silent (SNP) | VAF 18/85 reads (21%) | catalogued as rs1415265656, COSV50415629; called by muse, mutect2, varscan2
- EHD2 | c.1317C>T p.D439= | Silent (SNP) | VAF 11/73 reads (15%) | catalogued as rs543104405, COSV54406615; called by muse, mutect2, varscan2
- EIF2B5 | c.1413C>T p.G471= (on ENST00000647909; = p.G463= on NM_003907.3) | Silent (SNP) | VAF 10/96 reads (10%) | catalogued as COSV56603580; called by muse, mutect2
- FAM71C | c.129A>T p.A43= | Silent (SNP) | VAF 6/132 reads (5%) | catalogued as COSV60942542; called by muse, mutect2
- FANCA | c.2724C>G p.L908= | Silent (SNP) | VAF 8/72 reads (11%) | catalogued as COSV59795330; called by muse, mutect2, varscan2
- FBXO46 | c.1596G>A p.Q532= | Silent (SNP) | VAF 6/41 reads (15%) | catalogued as rs750676151, COSV58347770; called by muse, mutect2, varscan2
- FCRL6 | c.1239G>A p.T413= | Silent (SNP) | VAF 13/89 reads (15%) | catalogued as rs758807402, COSV58939852; called by muse, mutect2, varscan2
- FHDC1 | c.2769A>G p.S923= | Silent (SNP) | VAF 6/41 reads (15%) | catalogued as COSV52597351; called by muse, mutect2, varscan2
- FLCN | c.990C>A p.S330= | Silent (SNP) | VAF 15/168 reads (9%) | catalogued as COSV53256919; called by muse, mutect2
- FOXJ1 | c.375G>A p.S125= | Silent (SNP) | VAF 8/61 reads (13%) | catalogued as rs1487415490, COSV53941673; called by muse, mutect2, varscan2
- GCM2 | c.972T>C p.F324= | Silent (SNP) | VAF 38/197 reads (19%) | catalogued as rs1471712770, COSV65275042; called by muse, mutect2, varscan2
- GLMP | c.771C>T p.D257= | Silent (SNP) | VAF 25/199 reads (13%) | catalogued as rs778927170, COSV55293080; called by muse, mutect2, varscan2
- GOLM1 | c.582C>T p.N194= | Silent (SNP) | VAF 15/82 reads (18%) | catalogued as rs779822821, COSV57413606; called by muse, mutect2, varscan2
- GPC2 | c.873T>C p.P291= | Silent (SNP) | VAF 19/398 reads (5%) | catalogued as COSV52783785; called by muse, mutect2
- GPR151 | c.207G>A p.K69= | Silent (SNP) | VAF 22/57 reads (39%) | catalogued as rs762104399, COSV57033718; called by muse, mutect2, varscan2
- GPR61 | c.861G>T p.V287= | Silent (SNP) | VAF 15/95 reads (16%) | catalogued as COSV63983249; called by muse, mutect2, varscan2
- GRID2 | c.2430G>A p.Q810= | Silent (SNP) | VAF 37/103 reads (36%) | catalogued as rs757618780, COSV56171187; called by muse, mutect2, varscan2
- HIVEP1 | c.7605C>T p.P2535= | Silent (SNP) | VAF 15/116 reads (13%) | catalogued as rs1047584796, COSV65098496; called by muse, mutect2, varscan2
- HK2 | c.1878T>G p.S626= | Silent (SNP) | VAF 14/97 reads (14%) | catalogued as COSV51873065; called by muse, mutect2, varscan2
- IFT172 | c.2917C>T p.L973= | Silent (SNP) | VAF 21/152 reads (14%) | catalogued as rs1461476129, COSV53129386; called by muse, mutect2, varscan2
- INA | c.240G>A p.A80= | Silent (SNP) | VAF 11/49 reads (22%) | catalogued as COSV63975527; called by muse, mutect2, varscan2
- ITGA10 | c.645T>C p.H215= | Silent (SNP) | VAF 8/107 reads (7%) | catalogued as COSV100994782; called by muse, mutect2
- JAK1 | c.2433G>A p.R811= | Silent (SNP) | VAF 16/101 reads (16%) | catalogued as COSV61086950; called by muse, mutect2, varscan2
- JHY | c.225C>T p.D75= | Silent (SNP) | VAF 77/165 reads (47%) | catalogued as rs746783478, COSV56217805; called by muse, mutect2, varscan2
- KCNK2 | c.798T>C p.T266= (on ENST00000444842 / NM_001017425.3; = p.T251= on NM_014217.4) | Silent (SNP) | VAF 11/174 reads (6%) | catalogued as COSV67203156; called by muse, mutect2
- KCNS1 | c.990C>T p.G330= | Silent (SNP) | VAF 13/42 reads (31%) | catalogued as COSV60259273; called by muse, mutect2, varscan2
- KIAA1109 | c.15012A>G p.E5004= | Silent (SNP) | VAF 3/45 reads (7%) | catalogued as COSV52661806; called by muse, mutect2
- KLHL6 | c.432G>T p.R144= | Silent (SNP) | VAF 9/103 reads (9%) | catalogued as COSV58064401; called by muse, mutect2
- KMO | c.945A>G p.Q315= | Silent (SNP) | VAF 4/29 reads (14%) | catalogued as COSV63805630; called by muse, mutect2
- LAPTM4B | c.570C>A p.A190= (on ENST00000445593; = p.A99= on NM_018407.6) | Silent (SNP) | VAF 14/258 reads (5%) | catalogued as COSV71453707, COSV71453709; called by muse, mutect2
- LCE2C | c.162C>T p.S54= | Silent (SNP) | VAF 24/227 reads (11%) | catalogued as COSV64228230; called by muse, mutect2, varscan2
- LCT | c.3279A>C p.I1093= | Silent (SNP) | VAF 14/72 reads (19%) | catalogued as COSV51543782; called by muse, mutect2, varscan2
- LENG8 | c.1758C>T p.V586= | Silent (SNP) | VAF 6/122 reads (5%) | catalogued as rs142424676, COSV58725840, COSV58729500; called by muse, mutect2
- LIMA1 | c.1170C>T p.C390= | Silent (SNP) | VAF 18/128 reads (14%) | catalogued as rs760289112, COSV57963745; called by muse, mutect2, varscan2
- LINGO4 | c.543G>A p.K181= | Silent (SNP) | VAF 12/96 reads (13%) | catalogued as rs762914493, COSV59091150, COSV59091545; called by muse, mutect2, varscan2
- LRIG3 | c.273A>G p.A91= | Silent (SNP) | VAF 25/156 reads (16%) | catalogued as COSV57860646; called by muse, mutect2, varscan2
- LRP1B | c.12939G>A p.P4313= | Silent (SNP) | VAF 44/300 reads (15%) | catalogued as rs369634559, COSV101260542; called by muse, varscan2
- LRP1B | c.12885T>C p.N4295= | Silent (SNP) | VAF 24/222 reads (11%) | catalogued as COSV67184460; called by muse, varscan2
- LRP1B | c.8964T>G p.T2988= | Silent (SNP) | VAF 12/128 reads (9%) | catalogued as COSV67184468, COSV67218300; called by muse, mutect2
- LYST | c.204T>C p.C68= | Silent (SNP) | VAF 11/69 reads (16%) | catalogued as COSV67702982; called by muse, mutect2, varscan2
- MATN3 | c.1191C>A p.G397= | Silent (SNP) | VAF 6/29 reads (21%) | catalogued as COSV68099292; called by muse, mutect2, varscan2
- MGRN1 | c.948C>T p.C316= | Silent (SNP) | VAF 10/56 reads (18%) | catalogued as rs772459687, COSV52148077; called by muse, mutect2, varscan2
- MICAL2 | c.411T>C p.L137= | Silent (SNP) | VAF 8/117 reads (7%) | catalogued as COSV56316198; called by muse, mutect2
- MORN5 | c.435C>T p.N145= | Silent (SNP) | VAF 17/116 reads (15%) | catalogued as rs536933863, COSV65648421; called by muse, mutect2, varscan2
- MTNR1A | c.1026T>C p.N342= | Silent (SNP) | VAF 22/90 reads (24%) | catalogued as COSV56154899; called by muse, mutect2, varscan2
- MYPOP | c.1179C>T p.R393= | Silent (SNP) | VAF 9/75 reads (12%) | catalogued as rs138971632, COSV56192853; called by muse, mutect2, varscan2
- NCOA6 | c.792G>A p.Q264= | Silent (SNP) | VAF 7/62 reads (11%) | catalogued as rs772784924, COSV62860937; called by mutect2, varscan2
- NEIL3 | c.1674G>A p.K558= | Silent (SNP) | VAF 9/56 reads (16%) | catalogued as COSV52808369; called by muse, mutect2, varscan2
- NFASC | c.1773G>A p.T591= (on ENST00000339876 / NM_001378329.1; = p.T602= on NM_015090.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 34/173 reads (20%) | catalogued as rs748063109, COSV58358185; called by muse, mutect2, varscan2
- NFKBIZ | c.1560T>C p.C520= | Silent (SNP) | VAF 19/83 reads (23%) | catalogued as COSV58199251; called by muse, mutect2, varscan2
- NLRP1 | c.3675C>T p.A1225= | Silent (SNP) | VAF 5/68 reads (7%) | catalogued as COSV52558037; called by muse, mutect2
- NMRK1 | c.324T>C p.L108= | Silent (SNP) | VAF 14/66 reads (21%) | catalogued as COSV63111575; called by muse, mutect2, varscan2
- NOTCH3 | c.1068C>A p.V356= | Silent (SNP) | VAF 5/80 reads (6%) | catalogued as COSV54625883, COSV54626650; called by muse, mutect2
- NUDT6 | c.684C>T p.R228= | Silent (SNP) | VAF 10/150 reads (7%) | catalogued as rs1472923739, COSV52648044; called by muse, mutect2
- NXPE4 | c.438G>A p.A146= | Silent (SNP) | VAF 10/49 reads (20%) | catalogued as rs752391000, COSV64943364; called by muse, mutect2, varscan2
- NYAP2 | c.549C>T p.S183= | Silent (SNP) | VAF 22/181 reads (12%) | catalogued as rs180750663, COSV55997755; called by muse, mutect2, varscan2
- OPA1 | c.741C>T p.R247= (on ENST00000361510 / NM_130837.3; = p.R211= on NM_130832.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 8/122 reads (7%) | catalogued as COSV100655211; called by muse, mutect2
- OR1G1 | c.114G>A p.T38= | Silent (SNP) | VAF 39/98 reads (40%) | catalogued as rs757154641, COSV61029610; called by muse, mutect2, varscan2
- OR4K14 | c.69T>C p.L23= | Silent (SNP) | VAF 14/69 reads (20%) | catalogued as COSV59292052; called by muse, mutect2, varscan2
- PAPPA | c.2127A>G p.A709= | Silent (SNP) | VAF 28/187 reads (15%) | catalogued as COSV60277083; called by muse, mutect2, varscan2
- PCDH7 | c.2946C>T p.S982= | Silent (SNP) | VAF 15/60 reads (25%) | catalogued as rs372075213, COSV62336203; called by muse, mutect2, varscan2
- PCDHB11 | c.1149T>C p.C383= | Silent (SNP) | VAF 17/193 reads (9%) | catalogued as COSV61309762; called by muse, mutect2
- PCDHB5 | c.1794C>T p.N598= | Silent (SNP) | VAF 23/174 reads (13%) | catalogued as rs782428821, COSV99167733; called by muse, mutect2, varscan2
- PCDHB7 | c.555C>T p.S185= | Silent (SNP) | VAF 10/75 reads (13%) | catalogued as COSV50753737; called by muse, mutect2, varscan2
- PCDHGA10 | c.1899G>A p.A633= | Silent (SNP) | VAF 45/129 reads (35%) | catalogued as rs745950404, COSV53895267, COSV54030147; called by muse, mutect2, varscan2
- PCDHGB5 | c.1068G>A p.A356= | Silent (SNP) | VAF 15/89 reads (17%) | catalogued as rs773731727, COSV53895257; called by muse, mutect2, varscan2
- PDE6H | c.48T>C p.P16= | Silent (SNP) | VAF 5/35 reads (14%) | catalogued as COSV56760453; called by muse, mutect2, varscan2
- PDE7A | c.414T>C p.D138= (on ENST00000401827 / NM_001242318.3; = p.D112= on NM_002603.4) | Silent (SNP) | VAF 12/56 reads (21%) | catalogued as COSV101052618, COSV65152149; called by muse, mutect2, varscan2
- PDGFRB | c.1611C>A p.A537= | Silent (SNP) | VAF 6/96 reads (6%) | catalogued as COSV55800491, COSV55808574; called by muse, mutect2
- PDLIM5 | c.801T>C p.D267= | Silent (SNP) | VAF 7/80 reads (9%) | catalogued as COSV58744965; called by muse, mutect2
- PDZRN3 | c.1722C>T p.T574= | Silent (SNP) | VAF 5/39 reads (13%) | catalogued as COSV55190758; called by muse, mutect2, varscan2
- PFKM | c.1197T>C p.G399= | Silent (SNP) | VAF 6/150 reads (4%) | catalogued as COSV56655845; called by muse, mutect2
- PHF2 | c.1875G>A p.S625= | Silent (SNP) | VAF 16/76 reads (21%) | catalogued as rs142130095; called by muse, mutect2, varscan2
- PID1 | c.684C>T p.S228= (on ENST00000354069 / NM_001330156.1; = p.S226= on NM_017933.5) | Silent (SNP) | VAF 57/132 reads (43%) | catalogued as rs147151232; called by muse, mutect2, varscan2
- PIP4K2B | c.312A>G p.R104= | Silent (SNP) | VAF 10/62 reads (16%) | called by mutect2, varscan2
- PLAA | c.1590A>G p.T530= | Silent (SNP) | VAF 14/80 reads (18%) | catalogued as COSV68304476; called by muse, mutect2, varscan2
- PLGRKT | c.405A>G p.K135= | Silent (SNP) | VAF 4/90 reads (4%) | catalogued as COSV56348927; called by muse, mutect2
- PLXNB3 | c.3357G>A p.P1119= | Silent (SNP) | VAF 8/136 reads (6%) | catalogued as rs149200734, COSV62795346; called by muse, mutect2
- POF1B | c.1134A>G p.A378= | Silent (SNP) | VAF 3/45 reads (7%) | called by muse, mutect2
- POLR3B | c.1695A>G p.A565= | Silent (SNP) | VAF 23/82 reads (28%) | catalogued as COSV57275735; called by muse, mutect2, varscan2
- POU6F2 | c.420A>G p.T140= | Silent (SNP) | VAF 15/141 reads (11%) | catalogued as rs775727811, COSV68867248; called by muse, mutect2, varscan2
- PRKD3 | c.864C>T p.C288= | Silent (SNP) | VAF 11/84 reads (13%) | catalogued as COSV52209807; called by muse, mutect2, varscan2
- PSD3 | c.1798A>C p.R600= | Silent (SNP) | VAF 29/205 reads (14%) | catalogued as rs1396754856, COSV54066143; called by muse, mutect2, varscan2
- PTH2R | c.195T>C p.P65= | Silent (SNP) | VAF 5/81 reads (6%) | catalogued as COSV55913626; called by muse, mutect2
- PTK7 | c.702G>A p.V234= | Silent (SNP) | VAF 5/40 reads (13%) | catalogued as COSV57846170; called by muse, mutect2
- PTPN13 | c.7422A>G p.E2474= (on ENST00000411767 / NM_080683.3; = p.E2455= on NM_006264.3) | Silent (SNP) | VAF 10/52 reads (19%) | catalogued as COSV57402102, COSV57405177; called by muse, mutect2, varscan2
- PUM1 | c.819T>C p.G273= | Silent (SNP) | VAF 12/213 reads (6%) | catalogued as COSV57080972, COSV57081263; called by muse, mutect2
- RBM4 | c.306T>C p.G102= | Silent (SNP) | VAF 22/220 reads (10%) | catalogued as COSV59517905; called by muse, mutect2
- RHCG | c.177C>A p.R59= | Silent (SNP) | VAF 13/241 reads (5%) | catalogued as COSV51514273; called by muse, mutect2
- S1PR2 | c.108C>T p.A36= | Silent (SNP) | VAF 26/233 reads (11%) | catalogued as COSV100495279, COSV58485116; called by muse, mutect2, varscan2
- SAMD9L | c.723C>T p.V241= | Silent (SNP) | VAF 14/94 reads (15%) | catalogued as COSV59079260; called by muse, mutect2, varscan2
- SCGN | c.579T>C p.C193= | Silent (SNP) | VAF 14/176 reads (8%) | catalogued as COSV58544028; called by muse, mutect2
- SCN2A | c.111C>A p.P37= | Silent (SNP) | VAF 4/27 reads (15%) | catalogued as COSV51831009; called by muse, mutect2, varscan2
- SCN8A | c.5640A>G p.K1880= | Silent (SNP) | VAF 29/240 reads (12%) | catalogued as COSV61976100; called by muse, mutect2, varscan2
- SERINC1 | c.951A>G p.G317= | Silent (SNP) | VAF 23/155 reads (15%) | catalogued as COSV60101383; called by muse, mutect2, varscan2
- SFTPA2 | c.687A>C p.T229= | Silent (SNP) | VAF 38/176 reads (22%) | catalogued as COSV64882131; called by muse, mutect2, varscan2
- SIM1 | c.2226T>G p.T742= | Silent (SNP) | VAF 31/154 reads (20%) | catalogued as COSV53488772; called by muse, mutect2, varscan2
- SLIRP | c.45T>C p.S15= | Silent (SNP) | VAF 12/79 reads (15%) | catalogued as COSV53173651; called by muse, mutect2, varscan2
- SPOPL | c.573T>A p.G191= | Silent (SNP) | VAF 6/144 reads (4%) | catalogued as COSV54511631; called by muse, mutect2
- SPTA1 | c.5946A>G p.Q1982= | Silent (SNP) | VAF 80/397 reads (20%) | catalogued as COSV100934076, COSV63748587, COSV63750147; called by muse, mutect2
- SRPRA | c.600C>T p.N200= | Silent (SNP) | VAF 16/132 reads (12%) | catalogued as rs369914595; called by muse, mutect2, varscan2
- SUGP2 | c.1089T>C p.A363= | Silent (SNP) | VAF 11/76 reads (14%) | catalogued as COSV58254941; called by muse, mutect2, varscan2
- TCF23 | c.426G>A p.P142= | Silent (SNP) | VAF 33/354 reads (9%) | catalogued as rs1044613600, COSV56077846, COSV56078859; called by muse, mutect2, varscan2
- TMEM26 | c.924A>G p.A308= | Silent (SNP) | VAF 18/119 reads (15%) | catalogued as COSV53261086; called by muse, mutect2, varscan2
- TNIP1 | c.456T>C p.R152= | Silent (SNP) | VAF 18/65 reads (28%) | catalogued as COSV59303543; called by muse, mutect2, varscan2
- TNXB | c.5109C>T p.G1703= (on ENST00000647633; = p.G1456= on NM_019105.8 and 1 other RefSeq transcript) | Silent (SNP) | VAF 9/57 reads (16%) | catalogued as rs751200506, COSV64472893; called by muse, mutect2, varscan2
- TOP3B | c.621A>G p.L207= | Silent (SNP) | VAF 16/117 reads (14%) | catalogued as rs992249644, COSV64116296; called by muse, mutect2, varscan2
- TP53AIP1 | c.76A>C p.R26= | Silent (SNP) | VAF 7/136 reads (5%) | catalogued as COSV71688648; called by muse, mutect2
- TRMT2B | c.9C>A p.G3= | Silent (SNP) | VAF 9/74 reads (12%) | catalogued as COSV58618384; called by muse, mutect2, varscan2
- TSHZ2 | c.2676A>T p.S892= | Silent (SNP) | VAF 5/118 reads (4%) | catalogued as COSV61586699; called by muse, mutect2
- TUT1 | c.33G>A p.L11= | Silent (SNP) | VAF 13/84 reads (15%) | catalogued as rs1047117007, COSV53468650; called by muse, mutect2, varscan2
- UBN1 | c.1854T>C p.G618= | Silent (SNP) | VAF 20/168 reads (12%) | catalogued as rs778891793, COSV52165542; called by muse, mutect2, varscan2
- UBXN11 | c.1356T>C p.D452= (on ENST00000374221 / NM_183008.2; = p.D419= on NM_145345.2) | Silent (SNP) | VAF 16/116 reads (14%) | catalogued as COSV53326911; called by muse, mutect2, varscan2
- UHRF1BP1 | c.2160C>A p.A720= | Silent (SNP) | VAF 6/91 reads (7%) | catalogued as COSV51952509; called by muse, mutect2
- USP36 | c.2688G>A p.V896= | Silent (SNP) | VAF 20/165 reads (12%) | catalogued as rs1422886011, COSV61750062; called by muse, mutect2, varscan2
- USP39 | c.396T>C p.N132= | Silent (SNP) | VAF 23/108 reads (21%) | catalogued as rs373537425; called by muse, mutect2, varscan2
- VPS13D | c.4200A>C p.G1400= | Silent (SNP) | VAF 6/74 reads (8%) | catalogued as COSV50621414; called by muse, mutect2
- VPS18 | c.1956C>T p.C652= | Silent (SNP) | VAF 26/117 reads (22%) | catalogued as rs140514025; called by muse, mutect2, varscan2
- YES1 | c.435T>C p.N145= | Silent (SNP) | VAF 32/249 reads (13%) | catalogued as COSV58847787; called by muse, mutect2, varscan2
- YIPF4 | c.204T>C p.D68= | Silent (SNP) | VAF 22/101 reads (22%) | catalogued as COSV53212808; called by muse, mutect2, varscan2
- ZAP70 | c.237A>G p.G79= | Silent (SNP) | VAF 3/17 reads (18%) | catalogued as COSV53852362; called by muse, mutect2
- ZBTB1 | c.312A>G p.L104= | Silent (SNP) | VAF 7/130 reads (5%) | catalogued as COSV62437173; called by muse, mutect2
- ZC3H12A | c.645C>T p.R215= | Silent (SNP) | VAF 11/160 reads (7%) | catalogued as COSV66103854; called by muse, mutect2
- ZC3H12D | c.603G>T p.R201= | Silent (SNP) | VAF 14/91 reads (15%) | catalogued as COSV66323583; called by muse, mutect2, varscan2
- ZGRF1 | c.2934A>G p.T978= | Silent (SNP) | VAF 10/82 reads (12%) | catalogued as COSV52198883, COSV52203982; called by muse, mutect2, varscan2
- ZNF536 | c.462C>T p.G154= | Silent (SNP) | VAF 5/76 reads (7%) | catalogued as COSV62817879; called by muse, mutect2
- ZNF707 | c.627C>T p.C209= | Silent (SNP) | VAF 4/31 reads (13%) | catalogued as rs372016766; called by muse, mutect2, varscan2
- ZNF829 | c.258A>G p.L86= | Silent (SNP) | VAF 9/59 reads (15%) | catalogued as COSV66985605; called by muse, mutect2, varscan2
- ZZEF1 | c.6390T>C p.N2130= | Silent (SNP) | VAF 17/94 reads (18%) | catalogued as COSV67555842; called by muse, mutect2, varscan2
- KCNAB1 | c.276-129568G>A | Intron (SNP) | VAF 10/122 reads (8%) | catalogued as COSV56744375; called by muse, mutect2
- LDB3 | c.690-4811C>T | Intron (SNP) | VAF 48/353 reads (14%) | catalogued as rs750606592, COSV53951100; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MIR548A2 | n.17T>A | RNA (SNP) | VAF 7/63 reads (11%) | called by muse, mutect2, varscan2
- MIR596 | n.64C>T | RNA (SNP) | VAF 5/57 reads (9%) | called by muse, mutect2
- NDUFV3 | c.170-5430C>A | Intron (SNP) | VAF 32/183 reads (17%) | catalogued as COSV100446944; called by muse, mutect2, varscan2
- NRXN1 | c.772+1071T>G | Intron (SNP) | VAF 3/11 reads (27%) | catalogued as COSV68001410; called by muse, mutect2
- OR2W5 | n.947C>A | RNA (SNP) | VAF 29/167 reads (17%) | called by muse, mutect2, varscan2
- QKI | c.935-769C>A | Intron (SNP) | VAF 5/46 reads (11%) | catalogued as COSV99274570; called by muse, mutect2, varscan2
- RO60 | chr1:193091678 C>T | 3'Flank (SNP) | VAF 6/61 reads (10%) | catalogued as rs754775954, COSV66471629, COSV66471866; called by mutect2, varscan2
- RPL23AP42 | n.429T>A | RNA (SNP) | VAF 8/146 reads (5%) | called by muse, mutect2
- SFRP1 | c.544+1833G>A | Intron (SNP) | VAF 4/23 reads (17%) | catalogued as rs752571693, COSV99617084; called by muse, mutect2
- SRPK1 | c.1691-343A>T | Intron (SNP) | VAF 22/210 reads (10%) | catalogued as COSV60411147; called by muse, mutect2, varscan2
- TMEM183B | n.90C>T | RNA (SNP) | VAF 12/72 reads (17%) | catalogued as rs554167711; called by muse, mutect2, varscan2
- TTN | c.10360+3577C>T | Intron (SNP) | VAF 10/75 reads (13%) | catalogued as COSV59875263, COSV60279061; called by muse, mutect2, varscan2
- TTN | c.10360+1253T>G | Intron (SNP) | VAF 25/167 reads (15%) | catalogued as COSV59861821, COSV59870423; called by muse, varscan2
- VAPA | c.418-5462C>A | Intron (SNP) | VAF 10/38 reads (26%) | catalogued as COSV100486039; called by muse, mutect2
